Somatic mutation profile of tumor specimen TCGA-AG-A002-01A (aliquot TCGA-AG-A002-01A-01W-A00K-09) from TCGA case TCGA-AG-A002, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 35.8 years (13,090 days).
Specimen TCGA-AG-A002-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d104c42-783e-4630-9442-79b7b4a27616.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-A002-10A (Blood Derived Normal), aliquot TCGA-AG-A002-10A-01W-A00K-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b77415e6-52ca-47ca-aa01-5ddb92f94e0f

The open-access MAF lists 13,243 somatic variants for this specimen: 10,576 protein-altering or splice-affecting, 2,369 silent, 298 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8,879, Silent 2,369, Nonsense Mutation 1,368, Splice Site 197, Intron 143, Splice Region 70, RNA 69, 3'UTR 29, Frame Shift Ins 25, Frame Shift Del 22, 5'Flank 21, 5'UTR 20.

Variants (750 of 13,243; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACADM | c.1045C>T p.R349* | Nonsense Mutation (SNP) | VAF 37/97 reads (38%) | catalogued as rs148207467, CM940004; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTL6A | c.1129C>T p.R377W | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs868064163, COSV52023332; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 86/206 reads (42%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APOB | c.3997C>T p.R1333* | Nonsense Mutation (SNP) | VAF 78/260 reads (30%) | catalogued as rs121918383, CM880006; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APOB | c.1672C>T p.R558* | Nonsense Mutation (SNP) | VAF 35/96 reads (36%) | catalogued as rs878853970, COSV51937469; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATM | c.4396C>T p.R1466* | Nonsense Mutation (SNP) | VAF 62/139 reads (45%) | hotspot (GDC flag); catalogued as rs730881369, CM990210, COSV53723637, COSV99589850; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATM | c.5188C>T p.R1730* | Nonsense Mutation (SNP) | VAF 57/148 reads (39%) | catalogued as rs764389018, CM990211, COSV53730827; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BRAF | c.741T>G p.F247L | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs397509343, COSV56165267, COSV56257859; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BRCA2 | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 45/136 reads (33%) | catalogued as rs80358435, CM011914; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CACNA1A | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1064794263, CM065992, COSV64194216, COSV64200368; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CACNA1A | c.653C>T p.S218L | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs121908225, CM016081, COSV64197156; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CNGB3 | c.1063C>T p.R355* | Nonsense Mutation (SNP) | VAF 73/165 reads (44%) | catalogued as rs764742792, CM050554, COSV60684823; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- COL4A5 | c.920G>A p.G307D | Missense Mutation (SNP) | VAF 125/162 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104886082, CM026029, COSV60360998, COSV60362998; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CYP4V2 | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 65/163 reads (40%) | catalogued as rs369063468, CM130750; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DCX | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 203/257 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs122457137, CM010014, COSV57575924; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DEPDC5 | c.727C>T p.R243* | Nonsense Mutation (SNP) | VAF 52/135 reads (39%) | catalogued as rs772872014, CM146220, COSV56694430; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DIS3 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 66/151 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as rs139907646, COSV66705997; called by muse, mutect2, varscan2
- DOCK7 | c.5101C>T p.R1701* (on ENST00000635253 / NM_001367561.1; = p.R1670* on NM_033407.3) | Nonsense Mutation (SNP) | VAF 75/173 reads (43%) | catalogued as rs1419019482, COSV52004038; ClinVar: likely pathogenic; called by muse, varscan2
- EFHC1 | c.826C>T p.R276* | Nonsense Mutation (SNP) | VAF 53/136 reads (39%) | catalogued as rs796052414, COSV100932128; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EPHB1 | c.2227C>T p.R743W | Missense Mutation (SNP) | VAF 185/493 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs746798014, COSV67657824; called by muse, mutect2, varscan2
- EVC2 | c.2652G>A p.W884* | Nonsense Mutation (SNP) | VAF 28/82 reads (34%) | catalogued as rs981099037, CM098968; ClinVar: likely pathogenic; called by muse, varscan2
- FASTKD2 | c.1294C>T p.R432* | Nonsense Mutation (SNP) | VAF 92/236 reads (39%) | catalogued as rs118203917, CM085400, COSV52698959; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.1879C>T p.R627C | Missense Mutation (SNP) | VAF 60/190 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.446); catalogued as rs727503057, CM940760, COSV57315655; ClinVar: pathogenic; called by muse, mutect2
- FBN2 | c.3430G>A p.E1144K | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.298); catalogued as rs200060005, CM1412995, COSV52489870, COSV52518440; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1972C>T p.R658* (on ENST00000281708 / NM_001349798.2; = p.R578* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 92/231 reads (40%) | hotspot (GDC flag); catalogued as COSV55892162, COSV55908751; called by muse, mutect2, varscan2
- GAN | c.601C>T p.R201* | Nonsense Mutation (SNP) | VAF 111/259 reads (43%) | catalogued as rs119485090, CM020938, COSV101633963; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GCDH | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs886043840, CM002258, COSV55819744; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GRIN2A | c.2041C>T p.R681* | Nonsense Mutation (SNP) | VAF 77/208 reads (37%) | catalogued as rs397518472, CM138216, COSV58045574, COSV58045723; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HAMP | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 26/70 reads (37%) | catalogued as rs104894695, CM030043, COSV55885253, COSV55885498; ClinVar: pathogenic; called by muse, varscan2
- MGA | c.3724C>T p.R1242* | Nonsense Mutation (SNP) | VAF 27/56 reads (48%) | hotspot (GDC flag); catalogued as COSV54948051; called by muse, mutect2, varscan2
- MSH2 | c.2635-1G>A p.X879_splice | Splice Site (SNP) | VAF 29/51 reads (57%) | catalogued as rs267608020, CS036117, CS056118; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYOT | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 156/384 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs121908458, CM041092, CM041093; ClinVar: pathogenic; called by muse, varscan2
- NEXMIF | c.964C>T p.R322* | Nonsense Mutation (SNP) | VAF 199/258 reads (77%) | catalogued as rs1556016731, CM156012, COSV50023631; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.1318C>T p.R440* | Nonsense Mutation (SNP) | VAF 96/248 reads (39%) | hotspot (GDC flag); catalogued as rs778405030, CM950845, COSV62197118; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 99/241 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1466678870, COSV100647812, COSV62201290; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NGLY1 | c.1231C>T p.R411* | Nonsense Mutation (SNP) | VAF 63/164 reads (38%) | catalogued as rs146140738, COSV54984601; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PALB2 | c.541G>T p.E181* | Nonsense Mutation (SNP) | VAF 139/370 reads (38%) | catalogued as rs864622280; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PKHD1 | c.10444C>T p.R3482C | Missense Mutation (SNP) | VAF 103/239 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs148617572, CM032336; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- POGZ | c.712C>T p.R238* | Nonsense Mutation (SNP) | VAF 47/126 reads (37%) | catalogued as rs1557910873, COSV55034136; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 146/346 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 130/332 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM981671, CM993670, COSV64293729, COSV64297280; called by muse, mutect2, varscan2
- RLIM | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 68/88 reads (77%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.996); catalogued as rs1569309776, CM151027, COSV60325995, COSV60327625; ClinVar: pathogenic; called by muse, varscan2
- RP2 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 100/123 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1556318633, CM033008, CM077334, COSV54460861; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RPE65 | c.370C>T p.R124* | Nonsense Mutation (SNP) | VAF 101/224 reads (45%) | catalogued as rs61752877, CM983760; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- RPGRIP1 | c.154C>T p.R52* | Nonsense Mutation (SNP) | VAF 23/83 reads (28%) | catalogued as rs192003551, CM130723, COSV52847714; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SBF2 | c.3526C>T p.R1176* | Nonsense Mutation (SNP) | VAF 56/152 reads (37%) | catalogued as rs774667470, COSV99814989; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.383+1A>G p.X128_splice | Splice Site (SNP) | VAF 43/98 reads (44%) | catalogued as rs794726803, CS096247, CS096706, COSV57668946; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN2A | c.2995G>A p.E999K | Missense Mutation (SNP) | VAF 156/398 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as rs796053126, CM139611, COSV51835030; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SCN2A | c.4904G>A p.R1635Q | Missense Mutation (SNP) | VAF 53/600 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as rs1057520844, COSV51839526; ClinVar: pathogenic; called by muse, mutect2
- SETBP1 | c.666G>A p.W222* | Nonsense Mutation (SNP) | VAF 107/279 reads (38%) | catalogued as rs1391600900, COSV56320949; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC26A4 | c.269C>T p.S90L | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs370588279, CM030956, COSV55914262; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SLC45A2 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 67/163 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912621, CM040825, COSV99672894; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMARCD1 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 86/213 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57317934, COSV57318902; called by muse, mutect2, varscan2
- SPRED1 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 65/146 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057518150, COSV54438109, COSV54438678; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TBCK | c.1897+1G>A p.X633_splice (on ENST00000273980 / NM_001163436.4; = p.X570_splice on NM_033115.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 57/152 reads (38%) | catalogued as rs374319146, CS151082, COSV56757350; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TGFB2 | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 240/530 reads (45%) | catalogued as rs869025531, CM1210056, COSV65109013, COSV65110174; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TLK2 | c.1702C>T p.R568W (on ENST00000326270 / NM_001284333.2; = p.R546W on NM_006852.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as rs1283838287, COSV100409005, COSV58299682; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TTN | c.95964G>A p.W31988* (on ENST00000591111; = p.W24564* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 47/122 reads (39%) | catalogued as rs1559051231, COSV60028874; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TTN | c.11636C>A p.S3879* (on ENST00000591111; = p.S3833* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 80/185 reads (43%) | catalogued as rs370912401, CM1410923, COSV100632393; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TTPA | c.400C>T p.R134* | Nonsense Mutation (SNP) | VAF 59/118 reads (50%) | catalogued as rs121917851, CM981965, COSV52648579; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TUBB8 | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as rs869025272, CM160731, COSV100226026; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VHL | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.779); catalogued as rs367545984, CM951297, CM951298, COSV56554814; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- XYLT1 | c.1441C>T p.R481W | Missense Mutation (SNP) | VAF 76/179 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587777366, CM140714, COSV54480733, COSV54484140; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ZBTB24 | c.1369C>T p.R457* | Nonsense Mutation (SNP) | VAF 73/193 reads (38%) | catalogued as rs387907106, CM114082, COSV57781370; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.2905C>T p.P969S | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769823302, COSV59385969; called by muse, mutect2, varscan2
- A2M | c.2518G>T p.E840* | Nonsense Mutation (SNP) | VAF 100/230 reads (43%) | catalogued as COSV59385981; called by muse, mutect2, varscan2
- A2ML1 | c.201A>C p.E67D | Missense Mutation (SNP) | VAF 83/189 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as COSV55290090; called by muse, mutect2, varscan2
- A2ML1 | c.1688C>T p.S563F | Missense Mutation (SNP) | VAF 12/285 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55285671; called by muse, mutect2
- A2ML1 | c.3647C>T p.A1216V | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.584); catalogued as rs1041548414, COSV55285979; called by muse, mutect2, varscan2
- AADACL2 | c.381C>A p.F127L | Missense Mutation (SNP) | VAF 69/171 reads (40%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV62930264; called by muse, mutect2, varscan2
- AADACL3 | c.716A>C p.K239T | Missense Mutation (SNP) | VAF 192/533 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV60198857; called by muse, mutect2, varscan2
- AAK1 | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as rs766166655, COSV68643542; called by muse, mutect2, varscan2
- AARD | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375266231, COSV65599577, COSV65600510; called by muse, varscan2
- AARS1 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs765846298, COSV55747318; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AASS | c.1753G>T p.E585* | Nonsense Mutation (SNP) | VAF 82/213 reads (38%) | catalogued as COSV62789544; called by muse, mutect2, varscan2
- ABCA1 | c.2947G>A p.V983M | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1191482801, COSV66065232; called by muse, mutect2, varscan2
- ABCA1 | c.2726G>A p.R909Q | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.138); catalogued as rs574919140; called by muse, mutect2, varscan2
- ABCA10 | c.4041G>T p.K1347N | Missense Mutation (SNP) | VAF 117/272 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52224114; called by muse, mutect2, varscan2
- ABCA12 | c.7473G>T p.K2491N (on ENST00000272895 / NM_173076.3; = p.K2173N on NM_015657.3) | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0.023); catalogued as COSV99791735; called by muse, mutect2, varscan2
- ABCA12 | c.5956G>A p.D1986N (on ENST00000272895 / NM_173076.3; = p.D1668N on NM_015657.3) | Missense Mutation (SNP) | VAF 73/162 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.301); catalogued as rs746547558, COSV55949831; called by muse, mutect2, varscan2
- ABCA12 | c.5404G>A p.A1802T (on ENST00000272895 / NM_173076.3; = p.A1484T on NM_015657.3) | Missense Mutation (SNP) | VAF 96/253 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.102); catalogued as rs1559123915, COSV55977326; called by muse, mutect2, varscan2
- ABCA12 | c.4544G>A p.R1515Q (on ENST00000272895 / NM_173076.3; = p.R1197Q on NM_015657.3) | Missense Mutation (SNP) | VAF 68/164 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs774279263, CM1311790, COSV55948366; called by muse, varscan2
- ABCA12 | c.4393G>T p.D1465Y (on ENST00000272895 / NM_173076.3; = p.D1147Y on NM_015657.3) | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1559129128, COSV99790252; called by muse, varscan2
- ABCA13 | c.372A>C p.E124D | Missense Mutation (SNP) | VAF 99/260 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0.009); catalogued as COSV70027886; called by muse, mutect2, varscan2
- ABCA13 | c.1166C>A p.P389H | Missense Mutation (SNP) | VAF 94/258 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV70027907; called by muse, varscan2
- ABCA13 | c.1232G>A p.G411D | Missense Mutation (SNP) | VAF 134/319 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as rs557664531, COSV70027942; called by muse, varscan2
- ABCA13 | c.1568G>A p.S523N | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.773); catalogued as rs369781498, COSV70027974; called by muse, mutect2
- ABCA13 | c.2698A>C p.T900P | Missense Mutation (SNP) | VAF 91/208 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV70028014; called by muse, mutect2, varscan2
- ABCA13 | c.3988G>T p.A1330S | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as COSV70028023, COSV70041869; called by muse, mutect2, varscan2
- ABCA13 | c.4892G>T p.G1631V | Missense Mutation (SNP) | VAF 117/302 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as rs772829022, COSV70028026; called by muse, mutect2, varscan2
- ABCA13 | c.5636G>A p.R1879Q | Missense Mutation (SNP) | VAF 64/137 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs763421969, COSV70026133, COSV70042106; called by muse, mutect2, varscan2
- ABCA13 | c.6131G>T p.S2044I | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.203); catalogued as COSV101330203, COSV70028033; called by muse, mutect2, varscan2
- ABCA13 | c.12288G>T p.K4096N | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as COSV71287189; called by muse, mutect2, varscan2
- ABCA13 | c.13361G>A p.R4454H | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1280212847, COSV68946313; called by muse, mutect2
- ABCA13 | c.14183G>A p.R4728Q | Missense Mutation (SNP) | VAF 54/72 reads (75%) | SIFT tolerated (0.45); PolyPhen benign (0.013); catalogued as rs766502956, COSV68943781; called by muse, mutect2, varscan2
- ABCA13 | c.14548G>A p.A4850T | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.207); catalogued as rs746265472, COSV68946323; called by muse, mutect2, varscan2
- ABCA13 | c.14744G>A p.S4915N | Missense Mutation (SNP) | VAF 99/247 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs756698024, COSV68946330; called by muse, mutect2, varscan2
- ABCA3 | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as rs772668103, COSV57051667; called by muse, mutect2, varscan2
- ABCA4 | c.1094G>T p.R365I | Missense Mutation (SNP) | VAF 128/319 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs768881855; called by muse, mutect2, varscan2
- ABCA5 | c.4417C>T p.R1473* | Nonsense Mutation (SNP) | VAF 22/61 reads (36%) | catalogued as rs143193092; called by muse, mutect2, varscan2
- ABCA6 | c.3361C>T p.R1121C | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); catalogued as rs763645493, COSV52638238; called by muse, mutect2, varscan2
- ABCA6 | c.3083C>A p.S1028Y | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV99447437; called by muse, mutect2, varscan2
- ABCA6 | c.1302C>A p.F434L | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as COSV52645630; called by muse, mutect2, varscan2
- ABCA8 | c.2964G>A p.W988* | Nonsense Mutation (SNP) | VAF 23/64 reads (36%) | catalogued as rs759049261; called by muse, mutect2, varscan2
- ABCA8 | c.2900G>T p.R967I | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs758123773, COSV52204082; called by muse, mutect2, varscan2
- ABCA8 | c.975G>T p.K325N | Missense Mutation (SNP) | VAF 106/279 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs143207789, COSV52203749; called by muse, mutect2, varscan2
- ABCA9 | c.3848T>C p.I1283T | Missense Mutation (SNP) | VAF 147/392 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs988639249; called by muse, varscan2
- ABCA9 | c.163C>A p.H55N | Missense Mutation (SNP) | VAF 62/156 reads (40%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV60624284; called by muse, mutect2, varscan2
- ABCB1 | c.3644A>G p.Q1215R | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55950357; called by muse, mutect2, varscan2
- ABCB1 | c.2398G>T p.D800Y | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55951352; called by muse, mutect2, varscan2
- ABCB1 | c.857G>T p.R286I | Missense Mutation (SNP) | VAF 179/489 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.762); catalogued as COSV55944621, COSV55950626; called by muse, mutect2, varscan2
- ABCB11 | c.2569T>G p.L857V | Missense Mutation (SNP) | VAF 215/497 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV55589932; called by muse, mutect2, varscan2
- ABCB11 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.961); catalogued as rs199841445, CM117170; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCB4 | c.1846G>A p.E616K | Missense Mutation (SNP) | VAF 66/155 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs370195624, CM159632; called by muse, mutect2, varscan2
- ABCB5 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as rs368226947; called by muse, mutect2, varscan2
- ABCB5 | c.1078T>G p.F360V | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51708751; called by muse, mutect2
- ABCB5 | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs372984477; called by muse, mutect2, varscan2
- ABCB5 | c.2154+1G>A p.X718_splice (on ENST00000404938 / NM_001163941.2; = p.X273_splice on NM_178559.6) | Splice Site (SNP) | VAF 21/61 reads (34%) | catalogued as rs756265243, COSV51714310; called by muse, mutect2, varscan2
- ABCB6 | c.536A>C p.D179A | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.05); catalogued as COSV54695660; called by muse, mutect2, varscan2
- ABCB7 | c.1922C>T p.S641L (on ENST00000373394 / NM_001271696.3; = p.S642L on NM_004299.6) | Missense Mutation (SNP) | VAF 66/92 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs1002483499, COSV99504453; called by muse, mutect2, varscan2
- ABCB8 | c.1034G>A p.R345H (on ENST00000297504 / NM_001282291.2; = p.R328H on NM_007188.5) | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778422625, COSV52504302; called by muse, mutect2, varscan2
- ABCC1 | c.3343G>A p.A1115T | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as rs371062976; called by muse, mutect2, varscan2
- ABCC1 | c.4024C>T p.R1342W | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201020041; called by muse, mutect2, varscan2
- ABCC12 | c.3412G>A p.D1138N | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372800149; called by muse, mutect2, varscan2
- ABCC4 | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as rs781506182; called by muse, varscan2
- ABCC5 | c.502C>T p.R168* | Nonsense Mutation (SNP) | VAF 33/65 reads (51%) | catalogued as rs771305194, COSV55588908; called by muse, mutect2, varscan2
- ABCC8 | c.1299C>A p.F433L | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV56850515; called by muse, varscan2
- ABCC9 | c.2074G>T p.D692Y | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV53962541; called by muse, mutect2, varscan2
- ABCD2 | c.958C>A p.Q320K | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.439); catalogued as COSV100429668; called by muse, varscan2
- ABCF2 | c.949C>T p.R317W | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs759491541; called by muse, mutect2
- ABCG2 | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 111/258 reads (43%) | catalogued as COSV52942746, COSV52947706; called by muse, mutect2, varscan2
- ABCG2 | c.263C>T p.S88L | Missense Mutation (SNP) | VAF 75/194 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.063); catalogued as rs200415908; called by muse, mutect2, varscan2
- ABHD13 | c.176A>C p.K59T | Missense Mutation (SNP) | VAF 89/219 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.25); catalogued as COSV65534390; called by muse, mutect2, varscan2
- ABHD2 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 64/138 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs373748122; called by muse, mutect2, varscan2
- ABHD3 | c.1073C>T p.T358I | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV56676422; called by muse, mutect2, varscan2
- ABHD3 | c.469A>C p.I157L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as COSV56676434; called by muse, mutect2, varscan2
- ABI1 | c.958C>T p.R320* | Nonsense Mutation (SNP) | VAF 45/115 reads (39%) | catalogued as COSV61020748; called by muse, mutect2, varscan2
- ABL2 | c.1123G>T p.E375* (on ENST00000502732 / NM_007314.4; = p.E360* on NM_005158.5) | Nonsense Mutation (SNP) | VAF 76/171 reads (44%) | catalogued as COSV61013390; called by muse, mutect2, varscan2
- ABRAXAS2 | c.82T>G p.L28V | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53716806; called by muse, mutect2, varscan2
- ABT1 | c.309G>T p.K103N | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV51291177; called by muse, mutect2, varscan2
- AC090517.4 | c.1864G>T p.D622Y | Missense Mutation (SNP) | VAF 26/430 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1403438618, COSV99974532; called by muse, mutect2
- AC093155.3 | c.285+2T>C p.X95_splice | Splice Site (SNP) | VAF 83/206 reads (40%) | catalogued as COSV63350560; called by muse, mutect2, varscan2
- AC098582.1 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 76/181 reads (42%) | catalogued as rs1454346813; called by muse, mutect2, varscan2
- AC098582.1 | c.1659del p.K554Nfs*4 | Frame Shift Del (DEL) | VAF 76/206 reads (37%) | catalogued as COSV52019779; called by mutect2, pindel, varscan2
- AC134980.2 | c.815C>A p.S272Y | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs376814938; called by mutect2, varscan2
- ACACA | c.5302C>T p.R1768C | Missense Mutation (SNP) | VAF 351/907 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as rs1348929671; called by muse, mutect2, varscan2
- ACADL | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs758491059, COSV52052319; called by muse, mutect2, varscan2
- ACADM | c.279G>T p.E93D | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as COSV100897755; called by muse, mutect2, varscan2
- ACAN | c.2643C>A p.D881E | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.93); catalogued as COSV61359921; called by muse, mutect2, varscan2
- ACAN | c.4625T>G p.F1542C | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.854); catalogued as COSV61359923; called by muse, mutect2, varscan2
- ACAN | c.4991C>T p.S1664F | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61359925; called by muse, mutect2, varscan2
- ACAP1 | c.1729C>T p.R577* | Nonsense Mutation (SNP) | VAF 35/79 reads (44%) | catalogued as rs1364336849, COSV50136047; called by muse, varscan2
- ACAP2 | c.865T>C p.F289L | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58751705; called by muse, mutect2, varscan2
- ACBD3 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 61/173 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1278923333, COSV64729525; called by muse, mutect2, varscan2
- ACCS | c.55A>G p.T19A | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55458116; called by muse, mutect2, varscan2
- ACCSL | c.994C>A p.L332M | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV66581125; called by muse, mutect2, varscan2
- ACCSL | c.1631G>A p.R544H | Missense Mutation (SNP) | VAF 106/285 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as rs767298232, COSV66581134; called by muse, mutect2, varscan2
- ACE2 | c.1180A>C p.N394H | Missense Mutation (SNP) | VAF 79/106 reads (75%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV53024712; called by muse, mutect2, varscan2
- ACE2 | c.583C>T p.H195Y | Missense Mutation (SNP) | VAF 257/306 reads (84%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as rs764661406, COSV53024833; called by muse, varscan2
- ACE2 | c.506G>T p.R169I | Missense Mutation (SNP) | VAF 243/292 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53024399; called by muse, varscan2
- ACER1 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs777382846; called by muse, mutect2, varscan2
- ACHE | c.1503A>C p.K501N | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.094); catalogued as COSV53817265; called by muse, mutect2, varscan2
- ACKR3 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 61/160 reads (38%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.769); catalogued as rs763930150, COSV56022021; called by muse, mutect2, varscan2
- ACKR3 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 73/199 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1325541874, COSV56020269; called by muse, mutect2, varscan2
- ACKR4 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 107/381 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV51442454; called by muse, mutect2, varscan2
- ACKR4 | c.1013C>A p.S338Y | Missense Mutation (SNP) | VAF 95/411 reads (23%) | SIFT tolerated (0.78); PolyPhen benign (0.021); catalogued as COSV51442469; called by muse, mutect2, varscan2
- ACOT12 | c.1506C>A p.S502R | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.487); catalogued as rs770338667; called by muse, mutect2, varscan2
- ACOT12 | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 43/114 reads (38%) | catalogued as rs780095623, COSV56892749; called by muse, mutect2, varscan2
- ACOXL | c.384G>T p.K128N | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1427248571, COSV61324406; called by muse, varscan2
- ACP3 | c.313C>T p.R105* | Nonsense Mutation (SNP) | VAF 61/177 reads (34%) | catalogued as rs758538660, COSV60485862; called by muse, mutect2, varscan2
- ACP3 | c.1237G>T p.E413* | Nonsense Mutation (SNP) | VAF 250/659 reads (38%) | catalogued as COSV63639758; called by muse, mutect2, varscan2
- ACRBP | c.1426-1G>T p.X476_splice | Splice Site (SNP) | VAF 16/44 reads (36%) | catalogued as COSV57524027; called by muse, mutect2, varscan2
- ACRBP | c.886G>T p.D296Y | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV57522981, COSV57523775; called by muse, mutect2, varscan2
- ACSBG2 | c.331C>A p.L111M | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); catalogued as COSV99397647; called by muse, mutect2, varscan2
- ACSBG2 | c.1459G>A p.D487N | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777450290, COSV99397628; called by muse, mutect2, varscan2
- ACSL6 | c.1420G>T p.D474Y (on ENST00000379240; = p.D499Y on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57306564; called by muse, mutect2, varscan2
- ACSM1 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 163/384 reads (42%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs745476935, COSV54636001; called by muse, mutect2, varscan2
- ACSM4 | c.263A>C p.K88T | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV68067619; called by muse, mutect2, varscan2
- ACSM5 | c.1367G>A p.R456Q | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as rs369151501; called by muse, mutect2, varscan2
- ACSS3 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.202); catalogued as rs749390394; called by mutect2, varscan2
- ACTL7A | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs367596635; called by muse, mutect2, varscan2
- ACTL7B | c.144G>T p.K48N | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1189813942, COSV65927302; called by muse, mutect2, varscan2
- ACTN1 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.312); catalogued as rs368356125; called by muse, mutect2, varscan2
- ACTN4 | c.1665C>A p.F555L | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.314); catalogued as COSV53145650; called by mutect2, varscan2
- ACTR10 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 90/251 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.095); catalogued as rs554639681, COSV54298006; called by muse, mutect2, varscan2
- ACTR2 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 41/103 reads (40%) | catalogued as COSV53200814, COSV53203777; called by muse, mutect2, varscan2
- ACTR6 | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756214514; called by muse, mutect2, varscan2
- ACTR8 | c.1138C>T p.R380* | Nonsense Mutation (SNP) | VAF 14/29 reads (48%) | catalogued as rs201848227, COSV51636208; called by muse, mutect2, varscan2
- ACTR8 | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 66/135 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs747791798; called by muse, mutect2, varscan2
- ACTRT3 | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 9/25 reads (36%) | catalogued as COSV57754312; called by muse, mutect2, varscan2
- ACVR1 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 87/170 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55116621; called by muse, mutect2, varscan2
- ACVR2A | c.640G>T p.E214* | Nonsense Mutation (SNP) | VAF 72/184 reads (39%) | catalogued as COSV54021831; called by muse, mutect2, varscan2
- ACVR2A | c.1528G>T p.E510* | Nonsense Mutation (SNP) | VAF 34/108 reads (31%) | catalogued as COSV54018949; called by muse, mutect2, varscan2
- ADAM12 | c.1280G>A p.C427Y | Missense Mutation (SNP) | VAF 56/355 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64106036; called by muse, mutect2, varscan2
- ADAM12 | c.697G>T p.D233Y | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64101819; called by muse, mutect2
- ADAM15 | c.747C>A p.F249L | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55125821, COSV55126633; called by muse, mutect2, varscan2
- ADAM17 | c.631C>T p.R211* | Nonsense Mutation (SNP) | VAF 77/190 reads (41%) | catalogued as rs774040338, COSV60401866; called by muse, mutect2, varscan2
- ADAM18 | c.892G>T p.D298Y | Missense Mutation (SNP) | VAF 63/216 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.793); catalogued as COSV55855224; called by muse, mutect2, varscan2
- ADAM18 | c.916G>T p.D306Y | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV55846932; called by muse, mutect2, varscan2
- ADAM18 | c.1076A>T p.N359I | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV99694762; called by muse, varscan2
- ADAM18 | c.1772G>A p.G591E | Missense Mutation (SNP) | VAF 67/150 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.03); catalogued as COSV99694768; called by muse, mutect2, varscan2
- ADAM21 | c.1604C>A p.S535Y | Missense Mutation (SNP) | VAF 139/357 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as COSV50792374; called by muse, mutect2, varscan2
- ADAM22 | c.1154G>T p.R385I | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.1); catalogued as COSV55976070; called by muse, varscan2
- ADAM22 | c.1770G>T p.W590C | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55970820; called by muse, mutect2, varscan2
- ADAM22 | c.1846G>A p.E616K | Missense Mutation (SNP) | VAF 114/297 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.332); catalogued as COSV55976098, COSV55976380; called by muse, mutect2, varscan2
- ADAM28 | c.104G>T p.R35I | Missense Mutation (SNP) | VAF 194/465 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV56100235; called by muse, mutect2, varscan2
- ADAM28 | c.822G>T p.E274D | Missense Mutation (SNP) | VAF 74/180 reads (41%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.762); catalogued as rs1392638105, COSV56099330, COSV56100596; called by muse, mutect2, varscan2
- ADAM30 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 47/164 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs762560432, COSV65561010; called by muse, varscan2
- ADAM9 | c.2293G>T p.E765* | Nonsense Mutation (SNP) | VAF 250/550 reads (45%) | catalogued as COSV65960601; called by muse, varscan2
- ADAMTS1 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV53168803; called by muse, mutect2, varscan2
- ADAMTS12 | c.2161C>T p.L721F | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV104418949; called by muse, mutect2, varscan2
- ADAMTS14 | c.1473G>T p.Q491H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV64601778; called by muse, mutect2, varscan2
- ADAMTS17 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777382457; called by muse, mutect2, varscan2
- ADAMTS19 | c.1615C>A p.L539I | Missense Mutation (SNP) | VAF 170/416 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV50745607; called by muse, varscan2
- ADAMTS19 | c.1816G>T p.E606* | Nonsense Mutation (SNP) | VAF 30/128 reads (23%) | catalogued as COSV50733658; called by muse, varscan2
- ADAMTS19 | c.2923C>T p.R975* | Nonsense Mutation (SNP) | VAF 55/157 reads (35%) | catalogued as rs780852099, COSV50733755; called by muse, mutect2, varscan2
- ADAMTS20 | c.3389T>C p.V1130A | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV67130817; called by muse, mutect2, varscan2
- ADAMTS20 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143824237; called by muse, mutect2, varscan2
- ADAMTS4 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as rs546291574, COSV63487258; called by muse, mutect2, varscan2
- ADAMTS9 | c.3823C>T p.R1275W | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs371237082; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2809C>T p.R937* | Nonsense Mutation (SNP) | VAF 61/170 reads (36%) | catalogued as rs370313572; called by muse, mutect2, varscan2
- ADAMTSL4 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768459004, COSV54999382; called by muse, mutect2, varscan2
- ADAT2 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV52793311; called by muse, mutect2, varscan2
- ADCY10 | c.4345C>A p.L1449I | Missense Mutation (SNP) | VAF 84/229 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs749690491, COSV63239583, COSV63240944, COSV63245296; called by muse, varscan2
- ADCY2 | c.998G>T p.R333I | Missense Mutation (SNP) | VAF 71/167 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57866908; called by muse, mutect2, varscan2
- ADCY5 | c.1951G>T p.E651* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as rs1553726156; called by muse, mutect2
- ADCY7 | c.2506G>A p.E836K | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV54266435; called by muse, mutect2, varscan2
- ADCY9 | c.1174G>T p.E392* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | catalogued as COSV53573911, COSV53581701; called by muse, mutect2, varscan2
- ADCY9 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.144); catalogued as COSV53574790; called by muse, mutect2, varscan2
- ADGRA3 | c.2075G>A p.R692Q | Missense Mutation (SNP) | VAF 107/248 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs758572665, COSV51561845; called by muse, mutect2, varscan2
- ADGRA3 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 92/217 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as rs776366061, COSV57546319; called by muse, mutect2, varscan2
- ADGRB3 | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 46/108 reads (43%) | catalogued as COSV65384210; called by muse, varscan2
- ADGRB3 | c.4354C>T p.R1452W | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as rs1197657726, COSV53232994; called by muse, mutect2, varscan2
- ADGRE1 | c.336C>A p.F112L | Missense Mutation (SNP) | VAF 63/170 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs767441123, COSV51675119; called by muse, mutect2, varscan2
- ADGRE2 | c.1753C>A p.L585I | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.98); catalogued as COSV59693298; called by muse, mutect2, varscan2
- ADGRE2 | c.792C>A p.F264L | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs1473583876, COSV59693302; called by muse, mutect2, varscan2
- ADGRE2 | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.66); PolyPhen benign (0.013); catalogued as rs754889485, COSV59693104; called by muse, varscan2
- ADGRE5 | c.783C>A p.F261L (on ENST00000242786 / NM_078481.4; = p.F168L on NM_001784.5) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV54410264, COSV54412564; called by muse, mutect2, varscan2
- ADGRE5 | c.2204C>T p.A735V (on ENST00000242786 / NM_078481.4; = p.A642V on NM_001784.5) | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs780589696, COSV54391434; called by muse, mutect2, varscan2
- ADGRF4 | c.275G>T p.S92I | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV51955814; called by muse, mutect2
- ADGRF4 | c.875G>T p.S292I | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as COSV51952044; called by muse, mutect2, varscan2
- ADGRF5 | c.3920C>A p.S1307Y | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.069); catalogued as COSV51933379; called by muse, mutect2, varscan2
- ADGRF5 | c.284A>C p.N95T | Missense Mutation (SNP) | VAF 69/162 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51937609; called by muse, mutect2, varscan2
- ADGRG1 | c.906G>T p.K302N | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.143); catalogued as COSV65635573; called by muse, mutect2, varscan2
- ADGRG2 | c.1198G>T p.E400* (on ENST00000379869 / NM_001079858.3; = p.E397* on NM_005756.4) | Nonsense Mutation (SNP) | VAF 66/78 reads (85%) | catalogued as COSV100491977; called by muse, mutect2, varscan2
- ADGRG4 | c.222C>A p.F74L | Missense Mutation (SNP) | VAF 245/305 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV54955249; called by muse, mutect2, varscan2
- ADGRG4 | c.6682C>A p.L2228I | Missense Mutation (SNP) | VAF 97/123 reads (79%) | SIFT tolerated (0.1); PolyPhen benign (0.056); catalogued as COSV54949027, COSV54955261; called by muse, mutect2, varscan2
- ADGRG4 | c.8791C>T p.R2931W | Missense Mutation (SNP) | VAF 109/130 reads (84%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.635); catalogued as rs749245858, COSV54952424, COSV54952852; called by muse, mutect2, varscan2
- ADGRG6 | c.2209G>T p.D737Y | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV51588701; called by muse, mutect2, varscan2
- ADGRL2 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 59/170 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752679138, COSV54649550; called by muse, mutect2, varscan2
- ADGRL3 | c.994G>A p.D332N (on ENST00000506720 / NM_001322402.2; = p.D264N on NM_015236.6) | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72268204; called by muse, mutect2, varscan2
- ADGRL3 | c.2946G>T p.K982N (on ENST00000506720 / NM_001322402.2; = p.K914N on NM_015236.6) | Missense Mutation (SNP) | VAF 156/452 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV72230104; called by muse, mutect2
- ADGRL4 | c.920C>A p.P307H | Missense Mutation (SNP) | VAF 76/188 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV100876468, COSV66061402; called by muse, mutect2, varscan2
- ADGRL4 | c.726G>T p.K242N | Missense Mutation (SNP) | VAF 164/431 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as COSV66061404; called by muse, mutect2, varscan2
- ADGRV1 | c.1046A>G p.D349G | Missense Mutation (SNP) | VAF 115/276 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67984493; called by muse, mutect2, varscan2
- ADGRV1 | c.4207T>G p.L1403V | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.622); catalogued as COSV67984501; called by muse, mutect2, varscan2
- ADGRV1 | c.7454A>G p.N2485S | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67984509; called by muse, mutect2, varscan2
- ADGRV1 | c.11767G>T p.E3923* | Nonsense Mutation (SNP) | VAF 88/225 reads (39%) | catalogued as COSV67984514; called by muse, mutect2, varscan2
- ADGRV1 | c.12424C>T p.R4142W | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as rs534226753, COSV67978187; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRV1 | c.13282A>C p.T4428P | Missense Mutation (SNP) | VAF 150/382 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.399); catalogued as COSV67984518; called by muse, varscan2
- ADGRV1 | c.15268T>A p.F5090I | Missense Mutation (SNP) | VAF 93/231 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV67984523; called by muse, mutect2, varscan2
- ADGRV1 | c.17441C>T p.T5814I | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs766106265, COSV67984526; called by muse, mutect2, varscan2
- ADH1C | c.686A>C p.K229T | Missense Mutation (SNP) | VAF 277/723 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV72463452; called by muse, mutect2, varscan2
- ADIPOR1 | c.807C>T p.G269= | Splice Region (SNP) | VAF 48/116 reads (41%) | catalogued as rs763154047, COSV61851560; called by muse, mutect2, varscan2
- ADIPOR2 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777599853, COSV63947216; called by muse, mutect2, varscan2
- ADNP | c.2990C>A p.S997Y | Missense Mutation (SNP) | VAF 71/160 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as COSV62425259, COSV62426323; called by muse, mutect2, varscan2
- ADNP | c.1528C>A p.H510N | Missense Mutation (SNP) | VAF 88/219 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62425197; called by muse, varscan2
- ADNP2 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.291); catalogued as rs752046762, COSV100080899; called by muse, mutect2, varscan2
- ADNP2 | c.3192G>T p.K1064N | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as COSV51538442; called by muse, mutect2, varscan2
- ADORA2A | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748699595, COSV58378823; called by muse, varscan2
- ADORA2A | c.903G>T p.K301N | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as COSV58378828; called by muse, varscan2
- ADRA1B | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs571519472, COSV60701056; called by muse, mutect2, varscan2
- ADRB2 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60005591; called by muse, varscan2
- ADSS2 | c.1289G>A p.R430Q | Missense Mutation (SNP) | VAF 91/224 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as rs1210711318, COSV100836801, COSV63695060; called by muse, mutect2, varscan2
- AFDN | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 292/702 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.588); catalogued as rs747022102, COSV60050468; called by muse, mutect2, varscan2
- AFDN | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 176/442 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs761986153, COSV60060777; called by muse, mutect2, varscan2
- AFDN | c.3838C>T p.R1280* | Nonsense Mutation (SNP) | VAF 60/180 reads (33%) | catalogued as rs1326466203, COSV60038994; called by muse, varscan2
- AFG3L2 | c.293-1G>A p.X98_splice | Splice Site (SNP) | VAF 38/93 reads (41%) | catalogued as COSV99301913; called by muse, mutect2, varscan2
- AFM | c.110A>C p.K37T | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.109); catalogued as COSV56920021; called by muse, mutect2, varscan2
- AFM | c.881C>A p.S294Y | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.642); catalogued as COSV56921924; called by muse, varscan2
- AFTPH | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 165/213 reads (77%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as rs1179899621, COSV53217911; called by muse, mutect2, varscan2
- AGA | c.454C>A p.Q152K | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs991950983; called by muse, mutect2, varscan2
- AGAP1 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.736); catalogued as COSV58338374; called by muse, mutect2, varscan2
- AGAP2 | c.1501C>T p.R501C (on ENST00000547588 / NM_001122772.2; = p.R165C on NM_014770.4) | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs963328477, COSV57727810; called by muse, mutect2, varscan2
- AGBL1 | c.2401G>A p.A801T | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768659288, COSV66857146; called by muse, mutect2, varscan2
- AGBL1 | c.3278C>T p.A1093V | Missense Mutation (SNP) | VAF 119/337 reads (35%) | PolyPhen benign (0.025); catalogued as rs974899020, COSV66857149; called by muse, mutect2, varscan2
- AGBL2 | c.2400G>T p.E800D | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.257); catalogued as COSV54091418; called by muse, mutect2, varscan2
- AGFG2 | c.327G>T p.K109N | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV53543923; called by muse, mutect2, varscan2
- AGL | c.4460G>A p.R1487Q | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.085); catalogued as rs185681971, COSV54049327; called by muse, mutect2, varscan2
- AGMAT | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.814); catalogued as rs1343767993; called by muse, mutect2
- AGMO | c.682A>G p.N228D | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV61123261; called by muse, mutect2, varscan2
- AGO4 | c.85C>T p.R29* | Nonsense Mutation (SNP) | VAF 65/173 reads (38%) | catalogued as COSV64617106; called by muse, mutect2, varscan2
- AGPS | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 78/181 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51560637, COSV51563645; called by muse, mutect2, varscan2
- AGT | c.190G>T p.D64Y | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as rs374540090, COSV64184402; called by muse, mutect2, varscan2
- AGTPBP1 | c.1147G>A p.E383K (on ENST00000357081 / NM_001330701.2; = p.E343K on NM_015239.2) | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as rs538837935; called by muse, mutect2, varscan2
- AGTR1 | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 84/214 reads (39%) | catalogued as rs1417391173, COSV62557140; called by muse, mutect2, varscan2
- AGTR1 | c.784C>A p.L262M | Missense Mutation (SNP) | VAF 68/182 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0.201); catalogued as COSV62558042; called by muse, mutect2, varscan2
- AHI1 | c.3476C>A p.S1159Y | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (1); PolyPhen possibly damaging (0.556); catalogued as COSV55627157; called by muse, mutect2, varscan2
- AHI1 | c.1103T>G p.I368S | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV55627165; called by muse, mutect2, varscan2
- AHI1 | c.95A>C p.K32T | Missense Mutation (SNP) | VAF 109/270 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.425); catalogued as COSV55627175; called by muse, mutect2, varscan2
- AHNAK | c.11616G>T p.K3872N | Missense Mutation (SNP) | VAF 145/360 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV57212392; called by muse, mutect2, varscan2
- AHNAK | c.11164G>A p.E3722K | Missense Mutation (SNP) | VAF 99/216 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs750553868; called by muse, mutect2, varscan2
- AHNAK | c.8097G>T p.E2699D | Missense Mutation (SNP) | VAF 111/291 reads (38%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.99); catalogued as COSV57212400; called by muse, mutect2, varscan2
- AHNAK | c.5562G>T p.K1854N | Missense Mutation (SNP) | VAF 95/213 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.924); catalogued as COSV57202283, COSV57212409; called by muse, mutect2, varscan2
- AHNAK | c.2360T>G p.V787G | Missense Mutation (SNP) | VAF 59/148 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV57212415; called by muse, mutect2, varscan2
- AHNAK | c.117G>T p.Q39H | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV57212421; called by muse, mutect2
- AHNAK2 | c.15805C>A p.L5269I | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.248); catalogued as COSV60914601; called by muse, mutect2, varscan2
- AHNAK2 | c.14342C>A p.S4781Y | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as rs1161269246, COSV60914613; called by muse, mutect2, varscan2
- AHNAK2 | c.12761C>T p.T4254I | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.236); catalogued as rs758836684, COSV60914620; called by muse, mutect2, varscan2
- AHNAK2 | c.12406C>T p.P4136S | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60914626; called by muse, mutect2, varscan2
- AHNAK2 | c.9950C>T p.S3317L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as rs375227548; called by muse, varscan2
- AHR | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); catalogued as rs942138458; called by muse, mutect2, varscan2
- AHR | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54126014; called by muse, varscan2
- AK2 | c.397C>T p.R133* (on ENST00000354858; = p.R175* on NM_001625.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 7/68 reads (10%) | catalogued as rs1375379850, CD090009; called by muse, mutect2
- AK5 | c.277C>T p.R93W (on ENST00000354567 / NM_174858.3; = p.R67W on NM_012093.4) | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371926363; called by muse, mutect2
- AK9 | c.32C>A p.P11H | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV53424247; called by muse, mutect2, varscan2
- AKAP11 | c.2521G>A p.E841K | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.298); catalogued as COSV50299148; called by muse, mutect2, varscan2
- AKAP12 | c.2948G>T p.G983V | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as COSV53572595; called by muse, mutect2, varscan2
- AKAP12 | c.3844G>A p.E1282K | Missense Mutation (SNP) | VAF 119/251 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs368517285; called by muse, mutect2, varscan2
- AKAP13 | c.5322G>T p.E1774D (on ENST00000394518 / NM_007200.5; = p.E1778D on NM_006738.6) | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV63455988; called by muse, mutect2, varscan2
- AKAP17A | c.192C>A p.F64L | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as COSV58309491; called by muse, mutect2, varscan2
- AKAP3 | c.1747G>T p.E583* | Nonsense Mutation (SNP) | VAF 57/162 reads (35%) | catalogued as COSV99962107; called by muse, mutect2, varscan2
- AKAP3 | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 125/353 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as rs759457717; called by muse, mutect2, varscan2
- AKAP6 | c.2767G>T p.D923Y | Missense Mutation (SNP) | VAF 70/188 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55213360; called by muse, mutect2, varscan2
- AKAP6 | c.5104G>T p.E1702* | Nonsense Mutation (SNP) | VAF 95/247 reads (38%) | catalogued as COSV55221190, COSV55234497; called by muse, mutect2, varscan2
- AKAP6 | c.6635C>G p.A2212G | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.154); catalogued as rs201151556; called by muse, mutect2, varscan2
- AKAP9 | c.2167G>T p.E723* | Nonsense Mutation (SNP) | VAF 61/134 reads (46%) | catalogued as COSV62344827; called by muse, mutect2, varscan2
- AKAP9 | c.10516C>A p.L3506I (on ENST00000359028; = p.L3482I on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 134/301 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.65); catalogued as COSV62350106; called by muse, mutect2, varscan2
- AKIP1 | c.340A>G p.T114A | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs1180637437; called by muse, mutect2, varscan2
- AKNAD1 | c.2047G>T p.E683* | Nonsense Mutation (SNP) | VAF 45/113 reads (40%) | catalogued as COSV62196232; called by muse, mutect2, varscan2
- AKTIP | c.673_676del p.F225Tfs*5 | Frame Shift Del (DEL) | VAF 47/120 reads (39%) | catalogued as rs1347301445; called by pindel, varscan2
- AL121899.2 | c.215G>T p.R72I | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV67349873; called by muse, mutect2, varscan2
- AL645922.1 | c.17T>C p.V6A | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV54960474; called by muse, mutect2, varscan2
- AL645922.1 | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs751852076, COSV54960479; called by muse, mutect2, varscan2
- ALB | c.647C>T p.S216L | Missense Mutation (SNP) | VAF 16/223 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.037); catalogued as rs1485868409, COSV55737756; called by muse, mutect2
- ALDH1A3 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as CM147103, COSV60901623; called by muse, mutect2, varscan2
- ALDH1A3 | c.1462G>T p.E488* | Nonsense Mutation (SNP) | VAF 25/78 reads (32%) | catalogued as COSV100320448; called by muse, mutect2, varscan2
- ALDH1B1 | c.521A>C p.E174A | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66619645; called by muse, mutect2, varscan2
- ALDH1L1 | c.2701G>A p.E901K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.995); catalogued as rs550440307, COSV56410533, COSV56414628; called by muse, mutect2, varscan2
- ALDH1L2 | c.2431G>A p.V811M | Missense Mutation (SNP) | VAF 54/170 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs949861021; called by muse, mutect2, varscan2
- ALDH1L2 | c.2227G>A p.E743K | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as rs778654002, COSV51554714; called by muse, mutect2, varscan2
- ALDH1L2 | c.2140C>T p.R714* | Nonsense Mutation (SNP) | VAF 30/62 reads (48%) | catalogued as rs376554461, COSV51553888; called by muse, mutect2, varscan2
- ALDH4A1 | c.1219G>A p.A407T | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs145334067; called by muse, varscan2
- ALDH6A1 | c.908A>G p.N303S | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.338); catalogued as rs376852895; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALDH7A1 | c.1559C>T p.S520F | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554097854; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALDOC | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.415); catalogued as rs765845189, COSV52024310; called by muse, mutect2, varscan2
- ALG10B | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 123/303 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV100439924, COSV58143100; called by muse, mutect2, varscan2
- ALG10B | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 122/328 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774203610, COSV58143113; called by muse, varscan2
- ALG5 | c.925C>T p.R309* | Nonsense Mutation (SNP) | VAF 32/93 reads (34%) | catalogued as COSV53504958; called by muse, mutect2, varscan2
- ALLC | c.580G>T p.E194* | Nonsense Mutation (SNP) | VAF 28/53 reads (53%) | catalogued as rs372781677, COSV52994387; called by muse, mutect2, varscan2
- ALMS1 | c.1093G>T p.D365Y | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1229379546; called by muse, mutect2
- ALMS1 | c.6539G>T p.G2180V | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as COSV52509027; called by muse, mutect2
- ALMS1 | c.7796G>T p.R2599I | Missense Mutation (SNP) | VAF 140/348 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV52509038; called by muse, mutect2, varscan2
- ALMS1 | c.9334G>T p.E3112* | Nonsense Mutation (SNP) | VAF 127/288 reads (44%) | catalogued as COSV52509048; called by muse, mutect2, varscan2
- ALMS1 | c.12163C>T p.R4055W | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs569696567, COSV52509059; called by muse, mutect2, varscan2
- ALOX5 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.178); catalogued as rs560031203, COSV65550928; called by muse, varscan2
- ALOXE3 | c.746T>C p.M249T | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as rs1018138761; called by muse, mutect2, varscan2
- ALPG | c.174C>A p.F58L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.51); catalogued as COSV54965942; called by muse, mutect2, varscan2
- ALPK2 | c.6499G>A p.E2167K | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.306); catalogued as rs543965909, COSV64492583, COSV64495347; called by muse, mutect2, varscan2
- ALPK2 | c.5707G>T p.D1903Y | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770674676, COSV64492734; called by muse, mutect2, varscan2
- ALPK2 | c.2462C>A p.S821Y | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.325); catalogued as rs766680753, COSV64490725; called by muse, varscan2
- ALPK2 | c.569C>A p.P190H | Missense Mutation (SNP) | VAF 135/298 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV64492751, COSV64494034; called by muse, mutect2, varscan2
- ALPK3 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1226326851, COSV51930880; called by muse, mutect2
- ALPK3 | c.1499C>A p.S500Y | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV51931177, COSV51931863; called by muse, mutect2, varscan2
- ALS2 | c.3505A>G p.I1169V | Missense Mutation (SNP) | VAF 113/306 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as COSV51886764; called by muse, mutect2, varscan2
- AMACR | c.831G>T p.E277D | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV56871496; called by muse, mutect2
- AMD1 | c.289C>A p.L97I | Missense Mutation (SNP) | VAF 72/162 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.726); catalogued as rs779004856, COSV64387361; called by muse, mutect2, varscan2
- AMER1 | c.1219G>T p.E407* | Nonsense Mutation (SNP) | VAF 71/90 reads (79%) | catalogued as COSV57660035; called by muse, mutect2, varscan2
- AMER1 | c.674G>T p.R225I | Missense Mutation (SNP) | VAF 52/66 reads (79%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV57660048; called by muse, mutect2, varscan2
- AMFR | c.358G>T p.D120Y | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51921101; called by muse, mutect2, varscan2
- AMIGO1 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.76); PolyPhen benign (0.334); catalogued as COSV63990373; called by muse, mutect2, varscan2
- AMN1 | c.257A>C p.K86T | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.079); catalogued as COSV55671217; called by muse, mutect2, varscan2
- AMOTL1 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.34); catalogued as rs777229382, COSV54415331; called by muse, mutect2, varscan2
- AMPD1 | c.2140G>A p.E714K | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs374697989, COSV62415501; called by muse, mutect2, varscan2
- AMPD3 | c.2188C>T p.R730* (on ENST00000396553 / NM_001025389.2; = p.R739* on NM_000480.3) | Nonsense Mutation (SNP) | VAF 29/100 reads (29%) | catalogued as rs755071594, COSV67330872; called by muse, mutect2, varscan2
- AMPH | c.1541C>A p.T514N | Missense Mutation (SNP) | VAF 81/240 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV57743372; called by muse, mutect2, varscan2
- AMTN | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs776635978; called by muse, varscan2
- AMY2A | c.676T>G p.L226V | Missense Mutation (SNP) | VAF 222/1528 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.179); catalogued as rs1418295798; called by muse, varscan2
- ANAPC1 | c.4306G>A p.E1436K | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV61975859; called by muse, mutect2, varscan2
- ANAPC4 | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs201488708, COSV100194148; called by muse, mutect2, varscan2
- ANAPC4 | c.1714T>A p.F572I | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as COSV59543921; called by muse, mutect2, varscan2
- ANAPC4 | c.2015C>A p.S672Y | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.556); catalogued as COSV59543933; called by muse, mutect2, varscan2
- ANGPTL5 | c.1047C>A p.F349L | Missense Mutation (SNP) | VAF 202/535 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0.053); catalogued as rs780860743, COSV57532984; called by muse, mutect2, varscan2
- ANK1 | c.2408G>A p.R803Q | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs1285981952, COSV55885216; called by muse, mutect2, varscan2
- ANK2 | c.1616G>A p.R539Q | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as rs927869437; called by muse, mutect2, varscan2
- ANK2 | c.10925G>A p.R3642Q | Missense Mutation (SNP) | VAF 95/255 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757939990, COSV52166643; called by muse, varscan2
- ANK2 | c.11458C>T p.R3820W | Missense Mutation (SNP) | VAF 49/142 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.01); catalogued as rs199922285, COSV52161335; called by muse, mutect2, varscan2
- ANK3 | c.36G>T p.R12S | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.186); catalogued as COSV55063131; called by muse, mutect2, varscan2
- ANKAR | c.2846C>T p.S949L | Missense Mutation (SNP) | VAF 64/165 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as rs1210527940, COSV55612493; called by muse, mutect2, varscan2
- ANKEF1 | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 64/166 reads (39%) | catalogued as rs774211930, COSV65691928; called by muse, mutect2, varscan2
- ANKFN1 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 118/313 reads (38%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs765737413, COSV59459679; called by muse, mutect2, varscan2
- ANKFY1 | c.1498C>T p.R500W | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV58917304; called by muse, mutect2, varscan2
- ANKFY1 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 86/215 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs764800361, COSV58917315; called by muse, mutect2, varscan2
- ANKIB1 | c.2932C>A p.H978N | Missense Mutation (SNP) | VAF 74/168 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); catalogued as COSV56060984, COSV56061002; called by muse, mutect2, varscan2
- ANKLE1 | c.782C>T p.A261V (on ENST00000394458; = p.A207V on NM_152363.6) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.035); catalogued as rs769921478, COSV63920627; called by muse, mutect2, varscan2
- ANKLE2 | c.1295C>T p.S432L | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.673); catalogued as rs771035135, COSV61709248; called by muse, mutect2, varscan2
- ANKRA2 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 70/193 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as rs200934847; called by muse, mutect2, varscan2
- ANKRD11 | c.7599G>T p.E2533D | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs983273950, COSV56360257; called by muse, mutect2, varscan2
- ANKRD11 | c.4345G>A p.G1449R | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); catalogued as rs757947925, COSV56360264; called by muse, mutect2
- ANKRD11 | c.4177G>A p.E1393K | Missense Mutation (SNP) | VAF 99/224 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.454); catalogued as rs757166671, COSV56372184; called by muse, mutect2, varscan2
- ANKRD12 | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 155/361 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs747330128, COSV50824168; called by muse, mutect2, varscan2
- ANKRD12 | c.2305G>A p.D769N | Missense Mutation (SNP) | VAF 106/280 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.922); catalogued as COSV50830894; called by muse, mutect2, varscan2
- ANKRD12 | c.3922C>T p.R1308* | Nonsense Mutation (SNP) | VAF 145/390 reads (37%) | catalogued as rs766734820, COSV50819104; called by muse, mutect2, varscan2
- ANKRD12 | c.5456C>T p.S1819F | Missense Mutation (SNP) | VAF 137/365 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV50819436; called by muse, mutect2, varscan2
- ANKRD13A | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs769790065, COSV55676043; called by muse, mutect2, varscan2
- ANKRD13C | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); catalogued as rs1461634372, COSV52030719; called by muse, mutect2, varscan2
- ANKRD16 | c.922C>T p.R308* | Nonsense Mutation (SNP) | VAF 17/48 reads (35%) | catalogued as rs774806484, COSV51947720, COSV99510373; called by muse, mutect2, varscan2
- ANKRD17 | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 102/260 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1171099844; called by muse, mutect2, varscan2
- ANKRD26 | c.2682G>T p.K894N | Missense Mutation (SNP) | VAF 123/289 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as COSV65775295; called by muse, mutect2, varscan2
- ANKRD26 | c.2403G>T p.K801N | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as COSV65775298; called by muse, mutect2, varscan2
- ANKRD26 | c.2314G>T p.E772* | Nonsense Mutation (SNP) | VAF 99/223 reads (44%) | catalogued as COSV65775303; called by muse, mutect2, varscan2
- ANKRD27 | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 10/27 reads (37%) | catalogued as COSV60130451; called by muse, mutect2, varscan2
- ANKRD30A | c.863C>T p.A288V (on ENST00000611781; = p.A232V on NM_052997.2) | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as rs529585679, COSV64603435; called by muse, mutect2, varscan2
- ANKRD30A | c.1366G>T p.E456* (on ENST00000611781; = p.E400* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 48/136 reads (35%) | catalogued as COSV64608363; called by muse, mutect2, varscan2
- ANKRD35 | c.1848G>T p.E616D | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV62910290; called by muse, mutect2, varscan2
- ANKRD35 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as COSV62910286; called by muse, mutect2, varscan2
- ANKRD36B | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs768690692; called by mutect2, varscan2
- ANKRD36B | c.1291C>A p.P431T | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.29); catalogued as COSV51532194; called by muse, mutect2, varscan2
- ANKRD49 | c.647C>G p.A216G | Missense Mutation (SNP) | VAF 73/198 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV57060068; called by muse, mutect2, varscan2
- ANKRD55 | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 93/200 reads (47%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs759075872; called by muse, mutect2, varscan2
- ANKRD7 | c.631C>A p.L211I | Missense Mutation (SNP) | VAF 137/339 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.788); catalogued as COSV54554631; called by muse, mutect2, varscan2
- ANKS1B | c.849G>A p.E283= | Splice Region (SNP) | VAF 19/64 reads (30%) | catalogued as COSV61349421; called by muse, mutect2, varscan2
- ANKS6 | c.2551T>G p.F851V | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV62050136; called by muse, mutect2, varscan2
- ANKS6 | c.1622G>A p.R541Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as rs775835091, COSV62048792; called by muse, mutect2, varscan2
- ANO2 | c.2608G>A p.E870K (on ENST00000356134 / NM_001278597.3; = p.E874K on NM_001278596.3) | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.02); catalogued as COSV59021479; called by muse, mutect2, varscan2
- ANO2 | c.2129C>T p.T710I (on ENST00000356134 / NM_001278597.3; = p.T714I on NM_001278596.3) | Missense Mutation (SNP) | VAF 71/188 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as COSV59021006; called by muse, mutect2, varscan2
- ANO2 | c.2075T>C p.F692S (on ENST00000356134 / NM_001278597.3; = p.F696S on NM_001278596.3) | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.792); catalogued as COSV59021503; called by muse, mutect2, varscan2
- ANO2 | c.409G>T p.G137C (on ENST00000356134 / NM_001278597.3; = p.G141C on NM_001278596.3) | Missense Mutation (SNP) | VAF 66/171 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.599); catalogued as COSV100502475, COSV59021514; called by muse, mutect2, varscan2
- ANO3 | c.2356G>A p.E786K | Missense Mutation (SNP) | VAF 58/165 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56805617; called by muse, mutect2, varscan2
- ANO7 | c.771A>C p.Q257H (on ENST00000274979; = p.Q203H on NM_001370694.2) | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.758); catalogued as COSV51471311; called by muse, mutect2, varscan2
- ANO7 | c.2536C>A p.L846I (on ENST00000274979; = p.L792I on NM_001370694.2) | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.974); catalogued as rs756723413; called by muse, mutect2, varscan2
- ANPEP | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.78); PolyPhen benign (0.23); catalogued as rs774559825, COSV55589577; called by muse, mutect2, varscan2
- ANXA6 | c.1816G>A p.D606N | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs771610573, COSV62906625; called by muse, mutect2, varscan2
- AP002512.3 | c.538G>A p.V180I | Missense Mutation (SNP) | VAF 75/169 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.178); catalogued as rs367845258; called by muse, mutect2, varscan2
- AP1G2 | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.263); catalogued as rs759104775, COSV55337301, COSV55339360; called by muse, mutect2, varscan2
- AP2B1 | c.1111C>T p.R371* | Nonsense Mutation (SNP) | VAF 84/191 reads (44%) | catalogued as rs1404738425, COSV51997738; called by muse, mutect2, varscan2
- AP3S1 | c.125G>T p.R42I | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57474697; called by muse, mutect2, varscan2
- AP4E1 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs556357549, COSV55916749; called by muse, mutect2
- AP4E1 | c.705G>T p.E235D | Missense Mutation (SNP) | VAF 98/214 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as rs754437475, COSV55916257; called by muse, mutect2, varscan2
- AP4E1 | c.2401G>T p.E801* | Nonsense Mutation (SNP) | VAF 78/218 reads (36%) | catalogued as CM1511971; called by muse, varscan2
- AP4E1 | c.2532G>T p.K844N | Missense Mutation (SNP) | VAF 112/320 reads (35%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV55916095, COSV55916170; called by muse, varscan2
- APBA1 | c.2190G>T p.K730N | Missense Mutation (SNP) | VAF 57/123 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99595980, COSV99597291; called by muse, mutect2, varscan2
- APBA1 | c.1870G>A p.E624K | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs769199164, COSV55222649; called by muse, mutect2, varscan2
- APBB1 | c.1544G>T p.G515V | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV54981248; called by muse, mutect2, varscan2
- APC | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 97/254 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57327935, COSV99965567; called by muse, mutect2, varscan2
- APC | c.4199C>T p.S1400L | Missense Mutation (SNP) | VAF 79/184 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs267600319, CM995167, COSV57324455, COSV57326621, COSV57333132; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APC | c.4606G>T p.E1536* | Nonsense Mutation (SNP) | VAF 103/270 reads (38%) | catalogued as CM106376, COSV104439188, COSV57330094; called by muse, mutect2, varscan2
- APC | c.8282C>T p.P2761L | Missense Mutation (SNP) | VAF 78/219 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); catalogued as rs757874563; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APCDD1 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs115383241; called by muse, mutect2, varscan2
- APEX1 | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs778301776, COSV51657557; called by muse, mutect2, varscan2
- APEX1 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 99/231 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs374977590; called by muse, mutect2, varscan2
- API5 | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 17/230 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as rs1286304647; called by muse, mutect2
- APLF | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs150464758; called by muse, mutect2, varscan2
- APLF | c.1325C>T p.T442M | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as rs199832884, COSV58148267; called by muse, mutect2, varscan2
- APOB | c.10513C>A p.L3505I | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.575); catalogued as COSV51931434, COSV51934117; called by muse, mutect2, varscan2
- APOB | c.9107C>A p.S3036Y | Missense Mutation (SNP) | VAF 98/214 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV51925687; called by muse, mutect2, varscan2
- APOB | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.369); catalogued as rs780841518, COSV51922701; called by muse, mutect2, varscan2
- APOBEC3F | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs745372879, COSV57910629; called by muse, mutect2, varscan2
- APOBEC3G | c.958A>G p.R320G | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT tolerated (0.7); PolyPhen benign (0.014); catalogued as rs371126678; called by muse, mutect2, varscan2
- APOBEC4 | c.448C>A p.L150I | Missense Mutation (SNP) | VAF 70/197 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV58017582; called by muse, mutect2, varscan2
- APOH | c.1005G>A p.W335* | Nonsense Mutation (SNP) | VAF 99/235 reads (42%) | catalogued as COSV52772131; called by muse, mutect2, varscan2
- APPL1 | c.460del p.R154Efs*6 | Frame Shift Del (DEL) | VAF 24/56 reads (43%) | catalogued as rs749401724; called by mutect2, varscan2
- APPL1 | c.2002C>T p.R668W | Missense Mutation (SNP) | VAF 97/276 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1234269127, COSV99898088; called by muse, mutect2, varscan2
- APPL2 | c.757G>T p.E253* | Nonsense Mutation (SNP) | VAF 13/48 reads (27%) | catalogued as COSV51593514; called by muse, mutect2, varscan2
- AQR | c.3053G>A p.R1018Q | Missense Mutation (SNP) | VAF 61/181 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs370660482, COSV50031222; called by muse, mutect2, varscan2
- AQR | c.2108C>T p.S703L | Missense Mutation (SNP) | VAF 111/271 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.308); catalogued as rs776265279, COSV50033316; called by muse, mutect2, varscan2
- AQR | c.310G>T p.E104* | Nonsense Mutation (SNP) | VAF 22/153 reads (14%) | catalogued as COSV50033360; called by muse, mutect2, varscan2
- ARAP2 | c.978G>T p.E326D | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs752381896, COSV58284849; called by muse, mutect2, varscan2
- ARAP2 | c.36A>T p.K12N | Missense Mutation (SNP) | VAF 118/283 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.174); catalogued as COSV100394922, COSV58286147; called by muse, mutect2, varscan2
- ARCN1 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs367554879; called by muse, mutect2, varscan2
- AREL1 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 84/236 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.019); catalogued as rs1402405586, COSV62665635; called by muse, mutect2, varscan2
- ARF4 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.95); catalogued as rs747265204, COSV57714761; called by muse, mutect2, varscan2
- ARFGEF1 | c.3253G>T p.D1085Y | Missense Mutation (SNP) | VAF 115/252 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.285); catalogued as COSV99141445; called by muse, mutect2, varscan2
- ARFGEF2 | c.2905G>A p.D969N | Missense Mutation (SNP) | VAF 72/171 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.67); catalogued as rs944092192, COSV64213255; called by muse, mutect2, varscan2
- ARFGEF2 | c.5002C>T p.R1668* | Nonsense Mutation (SNP) | VAF 11/34 reads (32%) | catalogued as COSV64211634; called by muse, mutect2, varscan2
- ARFGEF3 | c.1024G>A p.V342M | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as rs141449825; called by muse, mutect2, varscan2
- ARFGEF3 | c.1961G>A p.R654Q | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs374061664; called by muse, mutect2, varscan2
- ARFGEF3 | c.4303G>T p.D1435Y | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV52456640; called by muse, mutect2, varscan2
- ARFGEF3 | c.5240C>T p.T1747M | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs139426666; called by muse, mutect2
- ARFGEF3 | c.6305T>G p.L2102R | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as COSV52456650; called by muse, mutect2
- ARGFX | c.943C>A p.L315I | Missense Mutation (SNP) | VAF 66/190 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.224); catalogued as rs768453486, COSV57682238; called by muse, mutect2, varscan2
- ARHGAP11A | c.772C>A p.L258I | Missense Mutation (SNP) | VAF 216/554 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV64380901; called by muse, mutect2, varscan2
- ARHGAP12 | c.1620G>T p.K540N | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60963006; called by muse, mutect2, varscan2
- ARHGAP18 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 101/265 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.195); catalogued as rs757913140, COSV63764480; called by muse, mutect2, varscan2
- ARHGAP19 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 95/222 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs765513484, COSV57392233; called by muse, mutect2, varscan2
- ARHGAP20 | c.2926G>T p.D976Y | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV52816940; called by muse, mutect2, varscan2
- ARHGAP20 | c.2405C>A p.S802Y | Missense Mutation (SNP) | VAF 95/214 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs748951088, COSV52816489; called by muse, mutect2, varscan2
- ARHGAP20 | c.2125G>A p.D709N | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.81); PolyPhen benign (0.01); catalogued as rs368565272; called by muse, mutect2, varscan2
- ARHGAP21 | c.3178G>T p.E1060* | Nonsense Mutation (SNP) | VAF 35/114 reads (31%) | catalogued as COSV57601656, COSV57609108; called by muse, mutect2, varscan2
- ARHGAP21 | c.3127G>A p.E1043K | Missense Mutation (SNP) | VAF 67/166 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs746024517; called by muse, mutect2, varscan2
- ARHGAP21 | c.1475G>T p.R492I | Missense Mutation (SNP) | VAF 149/362 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV57605454; called by muse, mutect2, varscan2
- ARHGAP25 | c.794C>T p.A265V (on ENST00000409202 / NM_001007231.3; = p.A257V on NM_014882.3) | Missense Mutation (SNP) | VAF 65/203 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs1481204393, COSV54898666; called by muse, mutect2, varscan2
- ARHGAP26 | c.2327C>T p.S776L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs182566788, COSV50831527; called by muse, mutect2, varscan2
- ARHGAP28 | c.1505C>T p.A502V (on ENST00000383472 / NM_001366230.1; = p.A343V on NM_001010000.3) | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs774266585, COSV51632571; called by muse, mutect2, varscan2
- ARHGAP29 | c.1940G>A p.R647Q | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.329); catalogued as rs748894382, COSV53110021; called by muse, mutect2, varscan2
- ARHGAP32 | c.3757G>A p.E1253K (on ENST00000310343 / NM_001378025.1; = p.E904K on NM_014715.4) | Missense Mutation (SNP) | VAF 65/169 reads (38%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.174); catalogued as rs768865360, COSV59847417; called by muse, mutect2, varscan2
- ARHGAP35 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68330965; called by muse, mutect2, varscan2
- ARHGAP35 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 64/167 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.04); catalogued as rs1322723304, COSV68330383, COSV68334239; called by muse, mutect2, varscan2
- ARHGAP44 | c.353G>T p.R118I | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV52393575, COSV52396962; called by muse, mutect2, varscan2
- ARHGAP5 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 153/370 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as COSV61535308; called by muse, mutect2, varscan2
- ARHGAP9 | c.26G>A p.S9N | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.107); catalogued as COSV62722370; called by muse, mutect2
- ARHGEF10 | c.2866C>T p.R956C (on ENST00000398564; = p.R931C on NM_014629.4) | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs772945845, COSV50648105; called by muse, mutect2, varscan2
- ARHGEF10L | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs371515222; called by muse, mutect2, varscan2
- ARHGEF12 | c.1669G>T p.V557L | Missense Mutation (SNP) | VAF 53/153 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV63104376; called by muse, mutect2, varscan2
- ARHGEF12 | c.2399G>T p.R800I | Missense Mutation (SNP) | VAF 116/293 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63104382; called by muse, mutect2, varscan2
- ARHGEF15 | c.2187-1G>A p.X729_splice | Splice Site (SNP) | VAF 18/54 reads (33%) | catalogued as COSV62725193; called by muse, mutect2, varscan2
- ARHGEF17 | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.023); catalogued as COSV55232232; called by muse, mutect2, varscan2
- ARHGEF26 | c.2126G>T p.R709I | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.999); catalogued as COSV100726549, COSV62846047; called by muse, mutect2, varscan2
- ARHGEF26 | c.2506G>T p.E836* | Nonsense Mutation (SNP) | VAF 109/263 reads (41%) | catalogued as COSV62846051; called by muse, mutect2, varscan2
- ARHGEF28 | c.3615G>T p.K1205N | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV55255266; called by muse, mutect2
- ARHGEF4 | c.227G>T p.R76I | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.445); catalogued as rs758730178; called by muse, mutect2, varscan2
- ARHGEF6 | c.2179G>T p.E727* | Nonsense Mutation (SNP) | VAF 149/192 reads (78%) | catalogued as COSV51687430; called by muse, mutect2, varscan2
- ARHGEF6 | c.2008G>A p.A670T | Missense Mutation (SNP) | VAF 54/67 reads (81%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); catalogued as rs775500896; called by muse, mutect2, varscan2
- ARID1B | c.2258C>T p.P753L | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.557); catalogued as rs754080772, COSV104368483; called by muse, mutect2, varscan2
- ARID2 | c.1126G>T p.E376* | Nonsense Mutation (SNP) | VAF 81/231 reads (35%) | catalogued as COSV100535402, COSV57594630, COSV57610501; called by muse, mutect2, varscan2
- ARID2 | c.3023C>A p.S1008Y | Missense Mutation (SNP) | VAF 88/214 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV57601269; called by muse, mutect2, varscan2
- ARID3B | c.1412A>G p.N471S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.368); catalogued as COSV60557511, COSV60558194; called by muse, mutect2
- ARID4A | c.3654A>C p.K1218N | Missense Mutation (SNP) | VAF 73/194 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62163470; called by muse, mutect2, varscan2
- ARID4B | c.937C>A p.L313I | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs1214414683; called by muse, mutect2, varscan2
- ARIH2 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.585); catalogued as COSV62704632; called by muse, mutect2, varscan2
- ARL1 | c.56G>A p.R19K | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55370276; called by muse, mutect2, varscan2
- ARL3 | c.543G>T p.K181N | Missense Mutation (SNP) | VAF 76/167 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as COSV99589040; called by muse, mutect2, varscan2
- ARL5A | c.391G>T p.E131* | Nonsense Mutation (SNP) | VAF 45/109 reads (41%) | catalogued as COSV99706604; called by muse, mutect2, varscan2
- ARL6IP1 | c.495G>T p.V165= | Splice Region (SNP) | VAF 34/76 reads (45%) | catalogued as rs748025123, COSV58614385; called by muse, mutect2
- ARMC2 | c.1096G>T p.D366Y | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0.04); PolyPhen benign (0.144); catalogued as rs1276266406, COSV64551097; called by muse, mutect2, varscan2
- ARMC2 | c.2552G>A p.R851Q | Missense Mutation (SNP) | VAF 177/426 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs757791916, COSV64550311, COSV64551406; called by muse, mutect2, varscan2
- ARMC3 | c.550C>T p.R184* | Nonsense Mutation (SNP) | VAF 32/109 reads (29%) | catalogued as rs201134940, COSV53063820; called by muse, mutect2, varscan2
- ARMC3 | c.1582G>T p.E528* | Nonsense Mutation (SNP) | VAF 40/102 reads (39%) | catalogued as COSV53057828; called by muse, varscan2
- ARMC3 | c.2527G>A p.A843T | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs200309888, COSV99957797; called by muse, varscan2
- ARMC8 | c.1256G>A p.R419Q (on ENST00000469044 / NM_001363941.2; = p.R405Q on NM_015396.6) | Missense Mutation (SNP) | VAF 72/176 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.194); catalogued as COSV58618205; called by muse, varscan2
- ARPC2 | c.434A>G p.H145R | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV55284794; called by muse, mutect2
- ARPIN | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs201638212, COSV62590317; called by muse, mutect2, varscan2
- ARRDC3 | c.1159C>T p.R387* | Nonsense Mutation (SNP) | VAF 63/162 reads (39%) | catalogued as COSV54364804, COSV54365403; called by muse, mutect2, varscan2
- ARSF | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 56/74 reads (76%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as rs746645956; called by muse, mutect2, varscan2
- ARSJ | c.713C>T p.S238F | Missense Mutation (SNP) | VAF 113/267 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866608001, COSV59537709; called by muse, mutect2, varscan2
- ARSK | c.1067C>A p.S356Y | Missense Mutation (SNP) | VAF 174/443 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101187535; called by muse, mutect2, varscan2
- ASAP3 | c.949C>T p.R317* | Nonsense Mutation (SNP) | VAF 5/13 reads (38%) | catalogued as rs760996705, COSV60874039; called by muse, mutect2, varscan2
- ASB12 | c.27G>T p.K9N | Missense Mutation (SNP) | VAF 27/38 reads (71%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV62856845, COSV62857964; called by muse, mutect2, varscan2
- ASB18 | c.221T>C p.L74P | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs762929132, COSV58233591; called by muse, mutect2, varscan2
- ASB4 | c.460C>A p.L154I | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs767015489, COSV57508485; called by muse, mutect2, varscan2
- ASB5 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.287); catalogued as COSV99642108; called by muse, mutect2, varscan2
- ASCC3 | c.1730G>A p.R577Q | Missense Mutation (SNP) | VAF 83/205 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0.069); catalogued as rs1020931997, COSV104410805; called by muse, mutect2, varscan2
- ASCC3 | c.938T>A p.I313N | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs751120994, COSV61226556; called by muse, mutect2, varscan2
- ASCC3 | c.333A>C p.E111D | Missense Mutation (SNP) | VAF 74/165 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.237); catalogued as COSV61228194; called by muse, mutect2, varscan2
- ASCL3 | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 59/149 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs560348439, COSV57941234; called by muse, mutect2, varscan2
- ASH1L | c.6451C>T p.R2151* (on ENST00000368346 / NM_001366177.2; = p.R2146* on NM_018489.3) | Nonsense Mutation (SNP) | VAF 36/108 reads (33%) | catalogued as COSV64207258; called by muse, mutect2, varscan2
- ASH1L | c.6232C>T p.R2078C (on ENST00000368346 / NM_001366177.2; = p.R2073C on NM_018489.3) | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as rs772388982, COSV64204956; called by muse, mutect2, varscan2
- ASH1L | c.2951G>A p.R984H | Missense Mutation (SNP) | VAF 86/232 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.747); catalogued as rs1187547460, COSV64207177; called by muse, mutect2, varscan2
- ASIC5 | c.1206G>T p.K402N | Missense Mutation (SNP) | VAF 55/185 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.062); catalogued as rs775723144, COSV101611096, COSV73332996; called by muse, varscan2
- ASPM | c.1668G>T p.K556N | Missense Mutation (SNP) | VAF 79/171 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.105); catalogued as COSV54129205; called by muse, mutect2, varscan2
- ASS1 | c.717G>T p.K239N | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as COSV61689234; called by muse, mutect2, varscan2
- ASTE1 | c.1838C>T p.S613L | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs947023459; called by muse, mutect2, varscan2
- ASTE1 | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 50/122 reads (41%) | catalogued as rs773437504, COSV53909044; called by muse, mutect2, varscan2
- ASTE1 | c.473C>A p.S158* | Nonsense Mutation (SNP) | VAF 46/125 reads (37%) | catalogued as COSV53910210; called by muse, mutect2, varscan2
- ASTE1 | c.51C>A p.F17L | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.284); catalogued as COSV99393992; called by muse, mutect2
- ASTL | c.1267A>C p.N423H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.135); catalogued as rs577986927; called by muse, mutect2, varscan2
- ASTN2 | c.1957C>T p.R653C (on ENST00000313400 / NM_001365069.1; = p.R602C on NM_014010.5) | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs759200691, COSV57763735, COSV57810099; called by muse, varscan2
- ASTN2 | c.1579G>A p.D527N (on ENST00000313400 / NM_001365069.1; = p.D476N on NM_014010.5) | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as rs976057171, COSV57747261; called by muse, mutect2, varscan2
- ASTN2 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs777574038, COSV57811894; called by muse, mutect2, varscan2
- ASXL2 | c.3665C>T p.T1222I | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV55458222; called by muse, mutect2, varscan2
- ASXL3 | c.1413G>T p.K471N | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.164); catalogued as COSV52464823; called by muse, mutect2, varscan2
- ASXL3 | c.1654C>A p.H552N | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV52464845, COSV52475460; called by muse, mutect2, varscan2
- ASXL3 | c.2410C>A p.L804M | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.365); catalogued as COSV52464865; called by muse, mutect2, varscan2
- ASXL3 | c.5468G>A p.R1823Q | Missense Mutation (SNP) | VAF 99/214 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.992); catalogued as rs201071954, COSV52462129; called by muse, mutect2, varscan2
- ASZ1 | c.799G>T p.D267Y | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as rs1466789937, COSV99498082; called by muse, mutect2, varscan2
- ATAD1 | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 55/116 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV57758105; called by muse, mutect2, varscan2
- ATAD2 | c.3184G>T p.E1062* | Nonsense Mutation (SNP) | VAF 58/164 reads (35%) | catalogued as COSV99784301; called by muse, mutect2, varscan2
- ATAD2B | c.4126A>C p.K1376Q | Missense Mutation (SNP) | VAF 117/279 reads (42%) | SIFT tolerated (0.86); PolyPhen benign (0.419); catalogued as COSV53198101; called by muse, mutect2, varscan2
- ATAD2B | c.2128G>T p.E710* | Nonsense Mutation (SNP) | VAF 25/67 reads (37%) | catalogued as COSV53198110; called by muse, mutect2, varscan2
- ATAD2B | c.1733G>T p.R578I | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV53198119; called by muse, mutect2, varscan2
- ATAD2B | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV53198126; called by muse, mutect2, varscan2
- ATAD2B | c.524G>T p.R175I | Missense Mutation (SNP) | VAF 138/318 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.537); catalogued as COSV53198138; called by muse, mutect2, varscan2
- ATAD5 | c.563C>A p.S188Y | Missense Mutation (SNP) | VAF 140/308 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as COSV58974208; called by muse, varscan2
- ATAD5 | c.4513G>T p.D1505Y | Missense Mutation (SNP) | VAF 64/165 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV58974229; called by muse, mutect2, varscan2
- ATCAY | c.832C>T p.R278W | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376658701; called by muse, mutect2, varscan2
- ATE1 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 83/209 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV56435876, COSV99817607; called by muse, varscan2
- ATF6 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 208/574 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as rs150872316; ClinVar: uncertain significance; called by muse, mutect2
- ATF6 | c.1892C>T p.S631L | Missense Mutation (SNP) | VAF 60/128 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771212825, COSV63406819; called by muse, mutect2, varscan2
- ATF7IP2 | c.273C>A p.F91L | Missense Mutation (SNP) | VAF 59/165 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs1361151528, COSV61092378, COSV61095454; called by muse, mutect2, varscan2
- ATG2B | c.1307C>A p.S436* | Nonsense Mutation (SNP) | VAF 101/252 reads (40%) | catalogued as COSV63423021; called by muse, mutect2, varscan2
- ATG4C | c.426A>C p.E142D | Missense Mutation (SNP) | VAF 90/238 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs747792609; called by muse, mutect2, varscan2
- ATG4C | c.1166G>A p.R389Q | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.059); catalogued as rs759584462, COSV58606506; called by muse, mutect2
- ATG4D | c.344A>G p.D115G | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV58762538; called by muse, mutect2, varscan2
- ATG5 | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 34/87 reads (39%) | catalogued as COSV100576662; called by muse, varscan2
- ATG9B | c.700C>T p.R234* | Nonsense Mutation (SNP) | VAF 22/50 reads (44%) | catalogued as rs781445782, COSV65057582, COSV65059052; called by muse, mutect2, varscan2
- ATL2 | c.712-1G>A p.X238_splice | Splice Site (SNP) | VAF 37/106 reads (35%) | catalogued as COSV60051772; called by muse, mutect2, varscan2
- ATL3 | c.851-1G>T p.X284_splice | Splice Site (SNP) | VAF 88/206 reads (43%) | catalogued as COSV60296161; called by muse, mutect2, varscan2
- ATM | c.1712C>A p.S571Y | Missense Mutation (SNP) | VAF 68/156 reads (44%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.694); catalogued as COSV53770272; called by muse, varscan2
- ATM | c.4222C>A p.L1408I | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV53727629, COSV53733404; called by muse, mutect2, varscan2
- ATMIN | c.1680G>T p.E560D | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV55145896; called by muse, mutect2, varscan2
- ATMIN | c.2133C>A p.F711L | Missense Mutation (SNP) | VAF 84/204 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.057); catalogued as COSV55145906; called by muse, mutect2, varscan2
- ATN1 | c.3455G>A p.R1152H | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1165161265, COSV57546776; called by muse, mutect2, varscan2
- ATP10A | c.2841G>T p.K947N | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV63515575; called by muse, mutect2, varscan2
- ATP10A | c.1713C>A p.F571L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63516875; called by muse, mutect2, varscan2
- ATP11B | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.251); catalogued as rs769443660, COSV100017797; called by muse, mutect2, varscan2
- ATP11B | c.1651G>T p.E551* | Nonsense Mutation (SNP) | VAF 29/78 reads (37%) | catalogued as rs1416014875, COSV60028238; called by muse, mutect2, varscan2
- ATP12A | c.1417A>C p.K473Q | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99516938; called by muse, mutect2, varscan2
- ATP12A | c.1583G>A p.R528H | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs1031193609, COSV54513986, COSV99516977; called by muse, varscan2
- ATP13A3 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 72/206 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV55464235; called by muse, mutect2, varscan2
- ATP13A5 | c.808G>T p.D270Y | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); catalogued as rs755794261, COSV60877217; called by muse, mutect2, varscan2
- ATP1A2 | c.1529G>A p.R510H | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs755353911, COSV63401911; called by muse, mutect2, varscan2
- ATP1A2 | c.2230G>A p.D744N | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as rs1131691922, COSV63403458; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP1A3 | c.3016G>A p.E1006K (on ENST00000545399 / NM_001256214.2; = p.E993K on NM_152296.5) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57485260; called by muse, mutect2, varscan2
- ATP1A3 | c.689G>A p.R230H (on ENST00000545399 / NM_001256214.2; = p.R217H on NM_152296.5) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1555865039, COSV57487321; called by muse, mutect2, varscan2
- ATP1A4 | c.589G>T p.D197Y | Missense Mutation (SNP) | VAF 47/176 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs146292275; called by muse, varscan2
- ATP2A3 | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as rs755685010, COSV59228846; called by muse, mutect2, varscan2
- ATP2B1 | c.1790G>A p.R597Q | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs1314253150, COSV53806452; called by muse, mutect2, varscan2
- ATP2B4 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 49/88 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs141117629; called by muse, mutect2, varscan2
- ATP2B4 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.319); catalogued as rs376933890; called by muse, mutect2, varscan2
- ATP2C1 | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 85/198 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs905995238, CM154426, COSV60752853, COSV60762794; called by muse, mutect2, varscan2
- ATP5F1A | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 59/149 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.634); catalogued as COSV56360278; called by muse, mutect2, varscan2
- ATP5F1C | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1370066640, COSV59622623; called by muse, mutect2, varscan2
- ATP5F1C | c.463G>T p.E155* | Nonsense Mutation (SNP) | VAF 58/174 reads (33%) | catalogued as COSV100184299; called by muse, varscan2
- ATP6AP2 | c.1039C>T p.R347* (on ENST00000378438; = p.R348* on NM_005765.3) | Nonsense Mutation (SNP) | VAF 50/54 reads (93%) | catalogued as COSV65797151; called by muse, mutect2, varscan2
- ATP6V0A1 | c.359G>T p.R120I | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV52873055; called by muse, mutect2, varscan2
- ATP6V0A4 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as rs867752659; called by muse, mutect2, varscan2
- ATP6V0A4 | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 138/373 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs147512254; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP6V0B | c.586C>A p.L196I | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.047); catalogued as COSV52542993; called by muse, mutect2, varscan2
- ATP6V1G2 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.717); catalogued as rs757650625; called by muse, mutect2, varscan2
- ATP8A1 | c.3029C>T p.A1010V | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.22); catalogued as rs1055141971, COSV52533843; called by muse, mutect2, varscan2
- ATP8A1 | c.1682G>A p.R561H | Missense Mutation (SNP) | VAF 109/298 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs556457468, COSV52550248; called by muse, mutect2, varscan2
- ATP8A1 | c.1582G>A p.D528N | Missense Mutation (SNP) | VAF 88/207 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs372291630; called by muse, mutect2, varscan2
- ATP8A1 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 72/171 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs749733890, COSV52533691; called by muse, mutect2, varscan2
- ATP8A2 | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 117/269 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54950041; called by muse, mutect2, varscan2
- ATP8A2 | c.2017C>A p.L673I | Missense Mutation (SNP) | VAF 86/266 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54950050; called by muse, mutect2, varscan2
- ATP8A2 | c.3236C>A p.P1079H | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54950060; called by muse, mutect2, varscan2
- ATP8B1 | c.3490C>T p.R1164* | Nonsense Mutation (SNP) | VAF 18/48 reads (38%) | catalogued as rs369054652, CM043833; called by muse, mutect2
- ATP8B1 | c.1935C>A p.I645= | Splice Region (SNP) | VAF 32/65 reads (49%) | catalogued as COSV52175388; called by muse, mutect2, varscan2
- ATP8B2 | c.536C>T p.A179V (on ENST00000672630; = p.A146V on NM_001005855.2) | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.244); catalogued as rs776939812, COSV59245184; called by muse, mutect2, varscan2
- ATP8B2 | c.1733C>T p.S578L (on ENST00000672630; = p.S545L on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751883997, COSV59244707; called by muse, mutect2, varscan2
- ATP8B4 | c.3214C>A p.L1072I | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0.013); catalogued as COSV104371713, COSV52712309, COSV52715044; called by muse, mutect2, varscan2
- ATP8B4 | c.1235G>T p.R412I | Missense Mutation (SNP) | VAF 82/204 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.035); catalogued as COSV52726883; called by muse, mutect2, varscan2
- ATP9A | c.3101G>A p.R1034Q | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.217); catalogued as rs1237540149, COSV58766082; called by muse, mutect2, varscan2
- ATP9A | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.386); catalogued as rs761097614, COSV100124509, COSV58762928; called by muse, mutect2, varscan2
- ATP9B | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs140291894, COSV56956164; called by muse, mutect2, varscan2
- ATPSCKMT | c.513G>T p.K171N | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.035); catalogued as COSV54726733; called by muse, mutect2, varscan2
- ATPSCKMT | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1437374941, COSV54726743; called by muse, mutect2, varscan2
- ATR | c.7088G>A p.R2363Q | Missense Mutation (SNP) | VAF 128/345 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs142918229, COSV63385448; called by muse, varscan2
- ATR | c.5657G>A p.R1886Q | Missense Mutation (SNP) | VAF 78/192 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1031921536, COSV63383829; called by muse, mutect2, varscan2
- ATR | c.4138G>T p.D1380Y | Missense Mutation (SNP) | VAF 159/370 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.068); catalogued as COSV63385516; called by muse, mutect2, varscan2
- ATR | c.3073C>T p.R1025C | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs980426116, COSV63387433; called by muse, mutect2, varscan2
- ATRN | c.2015C>T p.S672L | Missense Mutation (SNP) | VAF 94/223 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs760968702, COSV53524269; called by muse, mutect2, varscan2
- ATRN | c.2519G>A p.R840Q | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760816629; called by muse, varscan2
- ATRNL1 | c.1118G>T p.R373I | Missense Mutation (SNP) | VAF 188/521 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.21); catalogued as COSV61817900; called by muse, mutect2, varscan2
- ATRX | c.2342G>A p.R781Q | Missense Mutation (SNP) | VAF 243/302 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV64886569; called by muse, mutect2, varscan2
- ATXN1 | c.405C>A p.Y135* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as COSV55215391; called by muse, mutect2, varscan2
- ATXN10 | c.729-1G>T p.X243_splice | Splice Site (SNP) | VAF 91/270 reads (34%) | catalogued as COSV53294084, COSV99426696; called by muse, mutect2, varscan2
- ATXN2L | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs759450724, COSV57368378; called by muse, mutect2, varscan2
- ATXN2L | c.2269G>A p.D757N | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV57369688; called by muse, mutect2, varscan2
- ATXN3L | c.453C>A p.F151L | Missense Mutation (SNP) | VAF 51/65 reads (78%) | SIFT tolerated (0.06); PolyPhen benign (0.211); catalogued as COSV66075620; called by muse, mutect2, varscan2
- AUP1 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as rs755973491, COSV51206410; called by muse, mutect2, varscan2
- AUP1 | c.435C>A p.F145L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.31); catalogued as COSV51213739; called by muse, mutect2, varscan2
- AURKC | c.630G>T p.M210I (on ENST00000302804 / NM_001015878.2; = p.M176I on NM_003160.3) | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as COSV100249016; called by muse, mutect2, varscan2
- AVEN | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100145752; called by muse, mutect2, varscan2
- AVPR1A | c.974C>T p.S325L | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs750330664; called by muse, mutect2, varscan2
- AWAT2 | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 12/13 reads (92%) | catalogued as COSV52142874; called by muse, mutect2, varscan2
- AXDND1 | c.2227C>T p.R743* | Nonsense Mutation (SNP) | VAF 69/201 reads (34%) | catalogued as rs771074994, COSV62647551, COSV62648978; called by muse, mutect2, varscan2
- AXDND1 | c.2790G>T p.E930D | Missense Mutation (SNP) | VAF 90/239 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV62639544; called by muse, mutect2, varscan2
- AXL | c.128A>C p.N43T | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.993); catalogued as COSV56567801; called by muse, varscan2
- AXL | c.2046G>T p.E682D (on ENST00000301178 / NM_021913.5; = p.E673D on NM_001699.6) | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (1); PolyPhen probably damaging (0.98); catalogued as rs200876332; called by muse, varscan2
- AXL | c.2452G>A p.E818K (on ENST00000301178 / NM_021913.5; = p.E809K on NM_001699.6) | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs763066660, COSV56564019; called by muse, mutect2, varscan2
- B3GALNT1 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 91/212 reads (43%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as rs752083614, COSV57581127; called by muse, mutect2, varscan2
- B3GALT5 | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 99/228 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV58200685; called by muse, mutect2, varscan2
- B3GALT5 | c.862A>G p.K288E | Missense Mutation (SNP) | VAF 57/222 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.06); catalogued as COSV58198703; called by muse, varscan2
- B3GAT3 | c.563G>T p.G188V | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53882272; called by muse, mutect2, varscan2
- B3GLCT | c.1483C>T p.R495* | Nonsense Mutation (SNP) | VAF 30/86 reads (35%) | catalogued as rs770760169, COSV58456618; called by muse, varscan2
- B3GNT7 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs899688441, COSV55006371; called by mutect2, varscan2
- B3GNT7 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.386); catalogued as COSV55006316, COSV55006380; called by muse, mutect2, varscan2
- B4GALNT2 | c.1045G>T p.D349Y | Missense Mutation (SNP) | VAF 100/236 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV55926781; called by muse, mutect2, varscan2
- B4GALNT2 | c.1335G>T p.E445D | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.081); catalogued as COSV100302710; called by muse, mutect2, varscan2
- B4GALT3 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.596); catalogued as rs375294931; called by muse, mutect2, varscan2
- BABAM2 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 66/153 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.264); catalogued as rs1264465715; called by muse, mutect2, varscan2
- BACH1 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 165/419 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs1257840097, COSV54517914; called by muse, mutect2, varscan2
- BACH1 | c.1613G>A p.R538Q | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs750785692, COSV54518596; called by muse, mutect2, varscan2
- BAG5 | c.1315G>A p.D439N | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1488802882, COSV54571459; called by muse, mutect2, varscan2
- BAG5 | c.1168C>T p.R390* | Nonsense Mutation (SNP) | VAF 29/69 reads (42%) | catalogued as rs182208325, COSV54570184; called by muse, mutect2, varscan2
- BAMBI | c.134A>C p.K45T | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65002799; called by muse, mutect2, varscan2
- BAMBI | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 38/93 reads (41%) | catalogued as COSV65002824; called by muse, mutect2, varscan2
- BANF1 | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as rs1220650310, COSV56463510; called by muse, mutect2, varscan2
- BANP | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 23/55 reads (42%) | catalogued as COSV53737180; called by muse, mutect2, varscan2
- BANP | c.1043C>T p.P348L (on ENST00000286122; = p.P317L on NM_017869.4) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.014); catalogued as rs754021644, COSV53737190; called by muse, mutect2
- BATF | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54375717; called by muse, mutect2, varscan2
- BAZ1B | c.3572G>A p.R1191Q | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs782811497; called by muse, mutect2
- BAZ1B | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs1554575752, COSV59989118; called by muse, mutect2, varscan2
- BAZ2A | c.1480A>C p.K494Q | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV51633198, COSV51636196; called by muse, mutect2, varscan2
- BAZ2B | c.4684C>A p.L1562I | Missense Mutation (SNP) | VAF 48/480 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV58595224, COSV58600037; called by muse, mutect2, varscan2
- BAZ2B | c.3648C>A p.F1216L | Missense Mutation (SNP) | VAF 79/218 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV54275500; called by muse, mutect2, varscan2
- BAZ2B | c.2593C>T p.R865W | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.069); catalogued as rs748411774, COSV58600055; called by muse, mutect2, varscan2
- BBOF1 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 23/63 reads (37%) | catalogued as rs770987682, COSV67454921; called by muse, mutect2, varscan2
- BBOF1 | c.1072G>T p.E358* | Nonsense Mutation (SNP) | VAF 42/111 reads (38%) | catalogued as COSV67454925; called by muse, mutect2, varscan2
- BBOX1 | c.526T>G p.F176V | Missense Mutation (SNP) | VAF 74/157 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.29); catalogued as COSV54189134; called by muse, mutect2, varscan2
- BBS7 | c.2133C>A p.F711L | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV52657287; called by muse, mutect2, varscan2
- BBS7 | c.1487G>T p.R496I | Missense Mutation (SNP) | VAF 69/170 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.728); catalogued as rs750133083, COSV52657748; called by muse, varscan2
- BBS9 | c.1990G>T p.E664* (on ENST00000242067 / NM_001348036.1; = p.E624* on NM_014451.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 40/741 reads (5%) | catalogued as COSV54156361, COSV54158237; called by muse, mutect2
- BBX | c.1381C>T p.R461* | Nonsense Mutation (SNP) | VAF 124/341 reads (36%) | catalogued as COSV57883835; called by muse, mutect2, varscan2
- BCAS3 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 90/237 reads (38%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.921); catalogued as rs1383177608, COSV66773489; called by muse, mutect2, varscan2
- BCAS3 | c.1211C>T p.T404I | Missense Mutation (SNP) | VAF 49/601 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs915164864; called by muse, mutect2
- BCDIN3D | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 85/104 reads (82%) | catalogued as COSV100445465, COSV100445543; called by muse, mutect2, varscan2
- BCL2L13 | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.102); catalogued as rs749474060; called by muse, mutect2, varscan2
- BCL2L14 | c.13A>G p.S5G | Missense Mutation (SNP) | VAF 67/183 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV53786925; called by muse, mutect2, varscan2
- BCL9L | c.1389G>T p.K463N | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV52684095; called by muse, mutect2, varscan2
- BCLAF1 | c.2326G>T p.E776* | Nonsense Mutation (SNP) | VAF 122/292 reads (42%) | catalogued as COSV50356806; called by muse, varscan2
- BCLAF1 | c.2249G>A p.R750Q | Missense Mutation (SNP) | VAF 79/181 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.106); catalogued as rs78267720; called by muse, varscan2
- BCLAF1 | c.1129G>T p.D377Y | Missense Mutation (SNP) | VAF 92/313 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as rs755260641, COSV62141980; called by muse, mutect2, varscan2
- BDKRB2 | c.31C>A p.L11M | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.424); catalogued as rs924868565; called by muse, mutect2, varscan2
- BDP1 | c.332T>C p.V111A | Missense Mutation (SNP) | VAF 65/157 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.17); catalogued as COSV62431124; called by muse, mutect2, varscan2
- BDP1 | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 73/214 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.147); catalogued as rs756417651, COSV62431133; called by muse, mutect2, varscan2
- BDP1 | c.1616G>T p.R539I | Missense Mutation (SNP) | VAF 70/208 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV62431141; called by muse, mutect2, varscan2
- BDP1 | c.5530C>T p.R1844C | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773389976, COSV62429060; called by muse, mutect2, varscan2
- BEND4 | c.735T>G p.F245L | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.155); catalogued as COSV72469078; called by muse, mutect2, varscan2
- BEND4 | c.541C>A p.L181I | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV72469079; called by muse, mutect2, varscan2
- BEND5 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs201098567; called by muse, mutect2, varscan2
- BEND6 | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 102/239 reads (43%) | catalogued as rs769975234, COSV66068853; called by muse, mutect2, varscan2
- BEND7 | c.1373C>A p.S458Y | Missense Mutation (SNP) | VAF 16/35 reads (46%) | PolyPhen benign (0.056); catalogued as COSV61991607; called by muse, varscan2
- BFSP1 | c.1743G>T p.E581D | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV64900154; called by muse, mutect2, varscan2
- BHMT | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as rs111297335; called by muse, mutect2, varscan2
- BHMT | c.632C>A p.S211Y | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV57154456; called by muse, mutect2, varscan2
- BHMT2 | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 201/464 reads (43%) | catalogued as COSV54872301, COSV54874260; called by muse, mutect2, varscan2
- BICDL1 | c.1358G>A p.R453Q | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.071); catalogued as rs373275826, COSV57493070; called by muse, mutect2, varscan2
- BIN2 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758843494, COSV99909600; called by muse, mutect2, varscan2
- BIRC2 | c.1384C>T p.R462W | Missense Mutation (SNP) | VAF 82/173 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as rs779124253, COSV57161287; called by muse, mutect2, varscan2
- BIRC3 | c.20G>T p.S7I | Missense Mutation (SNP) | VAF 101/253 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as COSV54816597; called by muse, mutect2, varscan2
- BIRC3 | c.1102G>T p.E368* | Nonsense Mutation (SNP) | VAF 71/197 reads (36%) | catalogued as COSV54818367; called by muse, mutect2, varscan2
- BIRC6 | c.2005G>T p.E669* | Nonsense Mutation (SNP) | VAF 74/174 reads (43%) | catalogued as COSV70198768; called by muse, mutect2, varscan2
- BIRC6 | c.4145G>A p.R1382Q | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.8); PolyPhen benign (0.031); catalogued as rs777368785, COSV70196117; called by muse, mutect2, varscan2
- BIRC6 | c.9063A>C p.E3021D | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.108); catalogued as COSV70198774, COSV70203835; called by muse, mutect2, varscan2
- BIRC6 | c.11698G>T p.E3900* | Nonsense Mutation (SNP) | VAF 13/36 reads (36%) | catalogued as COSV70197254; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.81G>T p.E27D | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV57280657, COSV99958723; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4228G>A p.D1410N | Missense Mutation (SNP) | VAF 72/170 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.387); catalogued as COSV63245687; called by muse, mutect2, varscan2
- BLID | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 66/176 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); catalogued as COSV73340226; called by muse, mutect2, varscan2
- BLM | c.440C>A p.S147Y | Missense Mutation (SNP) | VAF 91/254 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV61922532; called by muse, mutect2, varscan2
- BLMH | c.1019A>G p.D340G | Missense Mutation (SNP) | VAF 160/388 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs184963100, COSV99913093; called by muse, mutect2, varscan2
- BLOC1S2 | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 194/498 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.885); catalogued as rs763047929; called by muse, varscan2
- BLZF1 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 135/315 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs1252405250, COSV61392922; called by muse, mutect2, varscan2
- BMERB1 | c.317C>A p.T106N | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs757365966, COSV55509794; called by muse, mutect2, varscan2
- BMP2 | c.1149G>T p.K383N | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66577759; called by muse, mutect2, varscan2
- BMP2K | c.3442G>A p.E1148K | Missense Mutation (SNP) | VAF 191/485 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); catalogued as rs754970059, COSV55008366; called by muse, mutect2, varscan2
- BMP5 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 64/160 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); catalogued as rs371743666, COSV100895985, COSV63707374; called by muse, varscan2
- BMPR2 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.542); catalogued as rs397514497, CM085278, COSV65807497; called by muse, mutect2, varscan2
- BMPR2 | c.2377A>G p.T793A | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.052); catalogued as COSV65809109; called by muse, mutect2, varscan2
- BMPR2 | c.2819C>A p.S940Y | Missense Mutation (SNP) | VAF 59/130 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1559074475, COSV101001318, COSV65809139; called by muse, mutect2, varscan2
- BMS1 | c.58A>C p.K20Q | Missense Mutation (SNP) | VAF 147/400 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100996449; called by muse, mutect2, varscan2
- BMS1 | c.1454G>A p.R485Q | Missense Mutation (SNP) | VAF 122/303 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs147587227; called by muse, mutect2, varscan2
- BMS1 | c.3184C>T p.R1062* | Nonsense Mutation (SNP) | VAF 134/358 reads (37%) | catalogued as rs759014042, COSV65733123; called by muse, mutect2, varscan2
- BNC1 | c.1974C>A p.F658L | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1378762756, COSV61757317; called by muse, mutect2, varscan2
- BOC | c.3241C>A p.P1081T | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.036); catalogued as COSV56347788; called by muse, varscan2
- BOD1L1 | c.5966G>A p.S1989N | Missense Mutation (SNP) | VAF 69/172 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.421); catalogued as rs755683006, COSV99239424; called by muse, mutect2, varscan2
- BOD1L1 | c.2718G>T p.E906D | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT tolerated (0.82); PolyPhen benign (0.011); catalogued as rs748637117; called by muse, mutect2, varscan2
- BOD1L1 | c.1939G>T p.E647* | Nonsense Mutation (SNP) | VAF 63/138 reads (46%) | catalogued as COSV50012922; called by muse, varscan2
- BORA | c.483T>C p.S161= (on ENST00000613797; = p.S86= on NM_024808.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 40/110 reads (36%) | catalogued as COSV64695215; called by muse, mutect2, varscan2
12,493 further variants in this file (9,826 protein-altering or splice-affecting, 2,369 silent, 298 other) are not listed here.
